Somatic mutation profile of cancer-model specimen HCM-BROD-0702-C43-85M (Adherent Cell Line, passage 14; aliquot HCM-BROD-0702-C43-85M-01D-A82H-36), derived from the metastatic tumor of HCMI case HCM-BROD-0702-C43, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 69.3 years (25,295 days).
Specimen HCM-BROD-0702-C43-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 14.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) be11e013-5e74-4156-af44-8403c79eaaba.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0702-C43-10A (Blood Derived Normal), aliquot HCM-BROD-0702-C43-10A-01D-A82H-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/237e0502-5d00-4191-9a64-045b093aa914

The open-access MAF lists 1,658 somatic variants for this specimen: 1,067 protein-altering or splice-affecting, 534 silent, 57 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 958, Silent 534, Nonsense Mutation 71, Intron 35, Splice Region 19, Frame Shift Del 10, Splice Site 8, 3'UTR 6, 5'UTR 6, 5'Flank 4, 3'Flank 3, RNA 3.

Variants (750 of 1,658; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 604/606 reads (100%) | hotspot (GDC flag); catalogued as rs121913388, CM014695, COSV58682746, COSV58721651; ClinVar: risk factor / likely pathogenic; called by muse, mutect2, varscan2
- KMT2D | c.14515+1G>T p.X4839_splice | Splice Site (SNP) | VAF 231/387 reads (60%) | catalogued as rs1555186232, COSV56497478; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NF1 | c.1393-1G>A p.X465_splice | Splice Site (SNP) | VAF 63/85 reads (74%) | catalogued as rs1131691131, COSV62193333, COSV62199307; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- RET | c.2689C>T p.R897* | Nonsense Mutation (SNP) | VAF 100/307 reads (33%) | catalogued as rs1060500759, CM035053, COSV60695393; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SCN1A | c.4934G>A p.R1645Q (on ENST00000303395 / NM_001202435.3; = p.R1634Q on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 259/404 reads (64%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs121917976, CM072001, CM1511233, COSV57662283; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACE | c.998T>C p.L333P | Missense Mutation (SNP) | VAF 174/675 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM120943; called by muse, varscan2
- ACLY | c.1804C>T p.P602S | Missense Mutation (SNP) | VAF 204/304 reads (67%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV61249256; called by muse, mutect2, varscan2
- ACSS3 | c.1594C>T p.P532S | Missense Mutation (SNP) | VAF 49/100 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as rs1247209581, COSV54084933; called by muse, varscan2
- ACTRT1 | c.778G>A p.E260K | Missense Mutation (SNP) | VAF 304/304 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370608808, COSV64420098; called by muse, mutect2, varscan2
- ADAM18 | c.1047G>A p.V349= | Splice Region (SNP) | VAF 51/51 reads (100%) | catalogued as COSV55843311, COSV55855552; called by muse, mutect2, varscan2
- ADAM22 | c.939G>A p.M313I | Missense Mutation (SNP) | VAF 104/244 reads (43%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.94); catalogued as COSV55971623; called by muse, mutect2, varscan2
- ADAM22 | c.2000G>A p.R667K | Missense Mutation (SNP) | VAF 118/249 reads (47%) | SIFT tolerated (0.85); PolyPhen benign (0.024); catalogued as rs368308668, COSV55971129; called by muse, mutect2, varscan2
- ADAM33 | c.1807G>A p.E603K | Missense Mutation (SNP) | VAF 249/476 reads (52%) | SIFT tolerated (0.21); PolyPhen benign (0.133); catalogued as rs1431651315, COSV62936895; called by muse, mutect2, varscan2
- ADAMTS20 | c.5491C>T p.P1831S | Missense Mutation (SNP) | VAF 128/211 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.668); catalogued as COSV67135971; called by muse, mutect2, varscan2
- ADAMTS20 | c.3199G>A p.E1067K | Missense Mutation (SNP) | VAF 219/374 reads (59%) | SIFT tolerated (0.32); PolyPhen benign (0.05); catalogued as rs879741559, COSV67130156; called by muse, mutect2, varscan2
- ADGRB3 | c.992G>A p.R331K | Missense Mutation (SNP) | VAF 334/336 reads (99%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.468); catalogued as COSV65407083; called by muse, mutect2, varscan2
- ADGRG4 | c.4877C>T p.S1626F | Missense Mutation (SNP) | VAF 359/359 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99794690; called by muse, mutect2, varscan2
- ADGRL2 | c.1750G>A p.E584K | Missense Mutation (SNP) | VAF 236/236 reads (100%) | SIFT tolerated (0.47); PolyPhen benign (0.05); catalogued as COSV54682105; called by muse, mutect2, varscan2
- AGTR2 | c.365C>T p.S122F | Missense Mutation (SNP) | VAF 234/235 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as COSV64156386; called by muse, mutect2, varscan2
- AICDA | c.506C>T p.S169L | Missense Mutation (SNP) | VAF 140/260 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.489); catalogued as CM064966, COSV57565492; called by muse, mutect2
- ALMS1 | c.4709C>T p.S1570F | Missense Mutation (SNP) | VAF 135/428 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.359); catalogued as rs765461259, COSV100041700; called by muse, mutect2, varscan2
- ALPI | c.1360G>A p.E454K | Missense Mutation (SNP) | VAF 320/452 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.553); catalogued as COSV55014023; called by muse, mutect2, varscan2
- ALX3 | c.416G>A p.G139E | Missense Mutation (SNP) | VAF 210/671 reads (31%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.554); catalogued as rs199713385; called by muse, mutect2, varscan2
- ANKRD30A | c.3385G>A p.E1129K (on ENST00000611781; = p.E1073K on NM_052997.2) | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.405); catalogued as COSV64607971; called by muse, mutect2, varscan2
- ANKRD30A | c.3913G>A p.E1305K (on ENST00000611781; = p.E1249K on NM_052997.2) | Missense Mutation (SNP) | VAF 94/184 reads (51%) | SIFT tolerated (0.4); PolyPhen benign (0.118); catalogued as rs867764777, COSV64614680, COSV64619316; called by muse, mutect2, varscan2
- ANKRD45 | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 329/330 reads (100%) | SIFT tolerated (0.33); PolyPhen benign (0.01); catalogued as COSV60960199; called by muse, mutect2, varscan2
- ANO3 | c.2941C>T p.P981S | Missense Mutation (SNP) | VAF 96/202 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV56782261; called by muse, mutect2, varscan2
- APOB | c.8083G>A p.D2695N | Missense Mutation (SNP) | VAF 282/420 reads (67%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV51933884; called by muse, mutect2, varscan2
- APOB | c.7880C>T p.P2627L | Missense Mutation (SNP) | VAF 81/259 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as COSV51939611; called by muse, mutect2, varscan2
- APOB | c.7524G>A p.M2508I | Missense Mutation (SNP) | VAF 122/378 reads (32%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as COSV51931107; called by muse, mutect2, varscan2
- AQP4 | c.824G>A p.G275E | Missense Mutation (SNP) | VAF 302/302 reads (100%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV67218974; called by muse, mutect2, varscan2
- ARHGAP5 | c.3253A>G p.M1085V | Missense Mutation (SNP) | VAF 121/358 reads (34%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as rs781136750, COSV61537320; called by muse, mutect2, varscan2
- ARRDC1 | c.701G>A p.R234Q | Missense Mutation (SNP) | VAF 570/571 reads (100%) | SIFT deleterious (0.02); PolyPhen benign (0.131); catalogued as rs138785809; called by muse, mutect2, varscan2
- ATP13A5 | c.1133G>A p.G378E | Missense Mutation (SNP) | VAF 179/294 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60877141; called by muse, mutect2, varscan2
- ATP2B2 | c.782G>A p.G261E | Missense Mutation (SNP) | VAF 116/227 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV59506905; called by muse, mutect2, varscan2
- B3GNT3 | c.14G>A p.R5Q | Missense Mutation (SNP) | VAF 92/382 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.019); catalogued as rs1448488810, COSV59439103; called by muse, mutect2, varscan2
- BANP | c.1096C>T p.P366S (on ENST00000286122; = p.P335S on NM_017869.4) | Missense Mutation (SNP) | VAF 630/630 reads (100%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.176); catalogued as COSV53737841; called by muse, mutect2, varscan2
- BAZ1A | c.292C>T p.R98C | Missense Mutation (SNP) | VAF 138/278 reads (50%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.926); catalogued as rs749785916; called by muse, mutect2, varscan2
- BCAM | c.529G>A p.G177R | Missense Mutation (SNP) | VAF 218/368 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs777617369; called by muse, varscan2
- BCAM | c.530G>A p.G177E | Missense Mutation (SNP) | VAF 241/404 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54304059; called by muse, mutect2, varscan2
- BCHE | c.1804C>T p.L602F | Missense Mutation (SNP) | VAF 50/154 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.072); catalogued as rs1279484125; called by muse, mutect2, varscan2
- BCLAF1 | c.848G>A p.R283Q | Missense Mutation (SNP) | VAF 40/154 reads (26%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.947); catalogued as rs145724464, COSV62140508; called by muse, mutect2, varscan2
- BPIFB1 | c.430G>A p.D144N | Missense Mutation (SNP) | VAF 441/619 reads (71%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV53606075; called by muse, mutect2, varscan2
- BRAT1 | c.2395C>T p.P799S | Missense Mutation (SNP) | VAF 240/515 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs762276921; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRD4 | c.3064C>T p.P1022S | Missense Mutation (SNP) | VAF 110/362 reads (30%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.007); catalogued as rs1338558685; called by muse, mutect2, varscan2
- BSN | c.6548C>T p.S2183F | Missense Mutation (SNP) | VAF 230/450 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as rs1457676519; called by muse, mutect2, varscan2
- BTNL3 | c.844G>A p.D282N | Missense Mutation (SNP) | VAF 136/418 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.048); catalogued as COSV61564634; called by muse, mutect2, varscan2
- C1orf105 | c.267G>A p.M89I | Missense Mutation (SNP) | VAF 272/272 reads (100%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs867969720, COSV62959341; called by muse, mutect2, varscan2
- C8B | c.1529G>A p.G510E | Missense Mutation (SNP) | VAF 105/323 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as rs766363026; called by muse, mutect2, varscan2
- CACNA1D | c.1222G>A p.E408K | Missense Mutation (SNP) | VAF 71/166 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV55452044; called by muse, mutect2, varscan2
- CACNA1G | c.3031G>A p.D1011N | Missense Mutation (SNP) | VAF 135/451 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs1197656926; called by muse, mutect2, varscan2
- CACNG5 | c.733G>A p.D245N | Missense Mutation (SNP) | VAF 870/1334 reads (65%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as rs1343811633; called by muse, mutect2
- CAMTA1 | c.1443G>A p.M481I | Missense Mutation (SNP) | VAF 423/630 reads (67%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV57924057; called by muse, mutect2, varscan2
- CAPN14 | c.1058G>A p.R353Q | Missense Mutation (SNP) | VAF 268/420 reads (64%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs896199846; called by muse, mutect2, varscan2
- CASP14 | c.156G>A p.M52I | Missense Mutation (SNP) | VAF 97/332 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV55666226; called by muse, mutect2, varscan2
- CCDC166 | c.1208C>T p.P403L | Missense Mutation (SNP) | VAF 300/894 reads (34%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.003); catalogued as rs1554616602; called by muse, mutect2, varscan2
- CCDC47 | c.356C>T p.P119L | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV56724473; called by muse, mutect2, varscan2
- CCKBR | c.862G>A p.E288K | Missense Mutation (SNP) | VAF 229/513 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.041); catalogued as CM972902, COSV58105007; called by muse, mutect2, varscan2
- CD163 | c.1922G>A p.G641E | Missense Mutation (SNP) | VAF 236/398 reads (59%) | SIFT tolerated (0.09); PolyPhen benign (0.209); catalogued as rs267603679, COSV63132851; called by muse, mutect2, varscan2
- CELF3 | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 530/532 reads (100%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.85); catalogued as rs200230999, COSV51884777; called by muse, mutect2, varscan2
- CEP126 | c.88C>T p.P30S | Missense Mutation (SNP) | VAF 153/444 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.897); catalogued as rs1241743534; called by muse, mutect2, varscan2
- CERKL | c.1172C>T p.S391L (on ENST00000339098 / NM_001030311.2; = p.S365L on NM_201548.5) | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as rs866794217, COSV59202458, COSV59202788, COSV59214606; called by muse, mutect2, varscan2
- CFAP299 | c.589C>T p.L197F | Missense Mutation (SNP) | VAF 101/101 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.281); catalogued as COSV100811630, COSV63881038; called by muse, mutect2, varscan2
- CFAP47 | c.1330C>T p.P444S | Missense Mutation (SNP) | VAF 64/64 reads (100%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.652); catalogued as rs1338138613; called by muse, mutect2, varscan2
- CFAP54 | c.4834C>T p.H1612Y | Missense Mutation (SNP) | VAF 65/119 reads (55%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.883); catalogued as COSV100733320; called by muse, mutect2, varscan2
- CFAP58 | c.2187A>T p.K729N | Missense Mutation (SNP) | VAF 138/247 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV104424443; called by muse, mutect2, varscan2
- CFAP61 | c.2398C>T p.R800W | Missense Mutation (SNP) | VAF 98/246 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.648); catalogued as rs764337986, COSV55636211; called by muse, mutect2, varscan2
- CHGA | c.952C>T p.R318W | Missense Mutation (SNP) | VAF 126/271 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); catalogued as rs896522084, COSV99381062; called by muse, mutect2, varscan2
- CHST15 | c.1099G>A p.D367N | Missense Mutation (SNP) | VAF 156/276 reads (57%) | SIFT tolerated (0.41); PolyPhen benign (0.023); catalogued as rs1486381652, COSV100654912; called by muse, mutect2, varscan2
- CIITA | c.2658-5C>T | Splice Region (SNP) | VAF 378/752 reads (50%) | catalogued as rs769134821; called by muse, mutect2
- CIT | c.5981C>T p.P1994L | Missense Mutation (SNP) | VAF 296/524 reads (56%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99951039; called by muse, mutect2, varscan2
- CLVS2 | c.859G>A p.E287K | Missense Mutation (SNP) | VAF 163/164 reads (99%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.015); catalogued as rs1351884730; called by muse, mutect2, varscan2
- CMSS1 | c.638C>T p.P213L | Missense Mutation (SNP) | VAF 108/348 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866665404, COSV70441251; called by muse, mutect2, varscan2
- CNGA2 | c.1279G>A p.E427K | Missense Mutation (SNP) | VAF 386/386 reads (100%) | SIFT deleterious (0.03); PolyPhen benign (0.411); catalogued as COSV100323473, COSV61703495; called by muse, mutect2, varscan2
- CNN2 | c.778C>T p.Q260* | Nonsense Mutation (SNP) | VAF 209/729 reads (29%) | catalogued as COSV54032908, COSV54034200; called by muse, mutect2, varscan2
- CNTN5 | c.3124A>T p.I1042F | Missense Mutation (SNP) | VAF 84/283 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV99678744; called by muse, mutect2, varscan2
- CNTNAP5 | c.1499C>T p.S500F | Missense Mutation (SNP) | VAF 93/270 reads (34%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.541); catalogued as COSV70483092; called by muse, mutect2, varscan2
- COL16A1 | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 243/376 reads (65%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.549); catalogued as COSV99057196; called by muse, mutect2, varscan2
- COL1A1 | c.2986C>T p.P996S | Missense Mutation (SNP) | VAF 180/522 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.271); catalogued as rs765775476; called by muse, varscan2
- COL3A1 | c.379G>A p.G127R | Missense Mutation (SNP) | VAF 102/315 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58590022; called by muse, mutect2, varscan2
- COL6A5 | c.4772G>A p.G1591E | Missense Mutation (SNP) | VAF 133/229 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55214567; called by muse, mutect2, varscan2
- CORO2B | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 160/353 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1377021598; called by muse, mutect2, varscan2
- CPAMD8 | c.1777C>T p.H593Y (on ENST00000651564; = p.H546Y on NM_015692.5) | Missense Mutation (SNP) | VAF 101/427 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0.212); catalogued as COSV52237862; called by muse, mutect2, varscan2
- CPNE3 | c.1429C>T p.P477S | Missense Mutation (SNP) | VAF 275/417 reads (66%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs140153543; called by muse, mutect2, varscan2
- CRACDL | c.735G>A p.S245= | Splice Region (SNP) | VAF 155/250 reads (62%) | catalogued as rs1003454801, COSV67410385; called by muse, mutect2, varscan2
- CRYBG2 | c.2365C>T p.P789S | Missense Mutation (SNP) | VAF 203/598 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); catalogued as rs565833646; called by muse, mutect2, varscan2
- CSMD3 | c.7852C>T p.H2618Y (on ENST00000297405 / NM_001363185.1; = p.H2514Y on NM_052900.3) | Missense Mutation (SNP) | VAF 209/341 reads (61%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV52281507; called by muse, mutect2, varscan2
- CSN3 | c.379G>A p.D127N | Missense Mutation (SNP) | VAF 267/267 reads (100%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.697); catalogued as COSV59243798; called by muse, mutect2, varscan2
- CSTF2T | c.1111G>A p.D371N | Missense Mutation (SNP) | VAF 156/373 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.785); catalogued as rs1228377004; called by muse, mutect2, varscan2
- CSTF3 | c.2018C>T p.P673L | Missense Mutation (SNP) | VAF 149/288 reads (52%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs750644457, COSV100124331; called by muse, mutect2, varscan2
- CTBP2 | c.820G>A p.G274S | Missense Mutation (SNP) | VAF 116/213 reads (54%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs775773778; called by muse, mutect2, varscan2
- CTH | c.709C>T p.R237C | Missense Mutation (SNP) | VAF 144/208 reads (69%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.947); catalogued as rs139166171; called by muse, mutect2, varscan2
- CTIF | c.587G>A p.R196Q | Missense Mutation (SNP) | VAF 298/298 reads (100%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.038); catalogued as rs1227058755; called by muse, mutect2, varscan2
- CTNNA2 | c.2816C>T p.S939L (on ENST00000402739 / NM_001282597.3; = p.S891L on NM_004389.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 174/281 reads (62%) | SIFT deleterious (0.04); PolyPhen benign (0.125); catalogued as rs1052098013, COSV58132864; called by muse, mutect2, varscan2
- CTNND2 | c.1876G>A p.D626N | Missense Mutation (SNP) | VAF 300/303 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs781670382, COSV58938331; called by muse, mutect2, varscan2
- CTPS1 | c.338T>C p.V113A | Missense Mutation (SNP) | VAF 99/276 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as rs779871759; called by muse, mutect2, varscan2
- CYP2C9 | c.748G>A p.E250K | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT tolerated (0.08); PolyPhen benign (0.171); catalogued as COSV53250549; called by muse, mutect2, varscan2
- CYP2C9 | c.1150G>A p.G384S | Missense Mutation (SNP) | VAF 56/168 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.755); catalogued as rs1331267899; called by muse, mutect2, varscan2
- CYP3A4 | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 79/172 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.602); catalogued as rs867315029; called by muse, mutect2, varscan2
- DAW1 | c.843G>A p.M281I | Missense Mutation (SNP) | VAF 170/252 reads (67%) | SIFT tolerated (0.39); PolyPhen benign (0.122); catalogued as rs1203464369; called by muse, mutect2, varscan2
- DCAF4L2 | c.659C>T p.S220L | Missense Mutation (SNP) | VAF 241/392 reads (61%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as rs180807114, COSV60478060; called by muse, mutect2, varscan2
- DCDC1 | c.3575G>A p.R1192Q (on ENST00000597505 / NM_001367979.1; = p.R299Q on NM_020869.3) | Missense Mutation (SNP) | VAF 143/279 reads (51%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.506); catalogued as rs758336719, COSV60307931; called by muse, mutect2, varscan2
- DCDC1 | c.2634G>A p.W878* | Nonsense Mutation (SNP) | VAF 52/105 reads (50%) | catalogued as rs755333408; called by muse, mutect2, varscan2
- DCLK3 | c.1264G>A p.E422K | Missense Mutation (SNP) | VAF 142/283 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs373605259, COSV69363137; called by muse, mutect2, varscan2
- DCLRE1B | c.1310C>T p.S437F | Missense Mutation (SNP) | VAF 142/466 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV65812447; called by muse, mutect2, varscan2
- DDX46 | c.1561C>T p.R521* | Nonsense Mutation (SNP) | VAF 64/224 reads (29%) | catalogued as rs1243349156, COSV62798775; called by muse, mutect2, varscan2
- DES | c.1231G>A p.G411R | Missense Mutation (SNP) | VAF 138/233 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.582); catalogued as COSV64660766; called by muse, mutect2, varscan2
- DIDO1 | c.5069C>T p.S1690L | Missense Mutation (SNP) | VAF 173/611 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.057); catalogued as rs1012637787; called by muse, mutect2, varscan2
- DISP1 | c.1672A>G p.M558V | Missense Mutation (SNP) | VAF 166/166 reads (100%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.45); catalogued as rs182626887; called by muse, mutect2, varscan2
- DKK2 | c.676G>A p.E226K | Missense Mutation (SNP) | VAF 221/222 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV53393923; called by muse, mutect2, varscan2
- DNAH11 | c.6202C>T p.R2068C | Missense Mutation (SNP) | VAF 72/166 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.246); catalogued as rs745332741, COSV60940114; called by muse, mutect2, varscan2
- DNAH12 | c.1067G>A p.R356Q | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT tolerated (0.61); PolyPhen benign (0.194); catalogued as rs748477425, COSV100244663, COSV60856753; called by muse, mutect2, varscan2
- DNAH5 | c.5648G>A p.R1883Q | Missense Mutation (SNP) | VAF 177/178 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs747514968, COSV54238992; called by muse, varscan2
- DNAH5 | c.4333G>A p.E1445K | Missense Mutation (SNP) | VAF 29/29 reads (100%) | SIFT tolerated (0.07); PolyPhen benign (0.255); catalogued as COSV54217879; called by muse, mutect2, varscan2
- DNAH7 | c.9326G>A p.G3109E | Missense Mutation (SNP) | VAF 103/349 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56754129; called by muse, mutect2, varscan2
- DNAH7 | c.4363G>A p.V1455I | Missense Mutation (SNP) | VAF 63/226 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs563306139; called by muse, mutect2, varscan2
- DNAH8 | c.5215C>T p.Q1739* | Nonsense Mutation (SNP) | VAF 196/198 reads (99%) | catalogued as COSV59425641; called by muse, mutect2, varscan2
- DNAI2 | c.1741G>A p.E581K | Missense Mutation (SNP) | VAF 408/615 reads (66%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as COSV100209828; called by muse, mutect2, varscan2
- DOT1L | c.1394C>T p.P465L | Missense Mutation (SNP) | VAF 218/583 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs778851336, COSV67109312; called by muse, mutect2, varscan2
- DPPA2 | c.730C>T p.H244Y | Missense Mutation (SNP) | VAF 133/409 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.611); catalogued as COSV72117929; called by muse, mutect2, varscan2
- DSG4 | c.2833G>A p.D945N | Missense Mutation (SNP) | VAF 170/171 reads (99%) | SIFT tolerated (0.34); PolyPhen benign (0.006); catalogued as COSV57387667; called by muse, mutect2, varscan2
- EFHB | c.1582C>T p.L528F | Missense Mutation (SNP) | VAF 86/162 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs750485784; called by muse, mutect2, varscan2
- EGR1 | c.679G>T p.G227C | Missense Mutation (SNP) | VAF 313/500 reads (63%) | SIFT tolerated (0.08); PolyPhen benign (0.159); catalogued as COSV53518133; called by muse, varscan2
- EGR1 | c.680G>T p.G227V | Missense Mutation (SNP) | VAF 317/506 reads (63%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs957347240; called by muse, varscan2
- ELAPOR2 | c.2971G>A p.E991K (on ENST00000450689 / NM_001142749.3; = p.E824K on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 94/194 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.64); catalogued as COSV51885157; called by muse, mutect2, varscan2
- ELAVL4 | c.1112C>T p.S371F | Missense Mutation (SNP) | VAF 173/273 reads (63%) | SIFT deleterious (0.01); PolyPhen benign (0.423); catalogued as COSV63914718; called by muse, mutect2, varscan2
- ELSPBP1 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 184/186 reads (99%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as rs1477014965, COSV60413242; called by muse, mutect2, varscan2
- EPB41L1 | c.2318C>T p.P773L | Missense Mutation (SNP) | VAF 279/447 reads (62%) | SIFT tolerated (0.32); PolyPhen benign (0.216); catalogued as COSV99150206; called by muse, mutect2, varscan2
- EPB41L4A | c.565C>T p.P189S | Missense Mutation (SNP) | VAF 184/274 reads (67%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99812782; called by muse, mutect2, varscan2
- EPHA6 | c.594G>A p.M198I | Missense Mutation (SNP) | VAF 106/224 reads (47%) | SIFT tolerated (0.47); PolyPhen benign (0.031); catalogued as rs1483105928, COSV67569289; called by muse, varscan2
- EPHA6 | c.1090G>A p.E364K | Missense Mutation (SNP) | VAF 121/210 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as COSV67585203; called by muse, mutect2, varscan2
- EPHA7 | c.2785G>A p.G929R | Missense Mutation (SNP) | VAF 149/149 reads (100%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as COSV65189714; called by muse, mutect2, varscan2
- EPS15 | c.967T>A p.S323T | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as COSV65545524; called by muse, mutect2, varscan2
- ERBB2 | c.1010C>T p.P337L | Missense Mutation (SNP) | VAF 91/360 reads (25%) | SIFT tolerated (0.37); PolyPhen benign (0.022); catalogued as COSV54062844; called by muse, mutect2, varscan2
- ERBB4 | c.3781G>A p.E1261K | Missense Mutation (SNP) | VAF 184/551 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.054); catalogued as rs1178525913, COSV61519164; called by muse, mutect2, varscan2
- ERICH3 | c.2098G>A p.D700N | Missense Mutation (SNP) | VAF 274/274 reads (100%) | SIFT tolerated (0.18); PolyPhen benign (0.025); catalogued as rs867387777; called by muse, mutect2, varscan2
- EVPL | c.4033C>T p.R1345W | Missense Mutation (SNP) | VAF 202/1347 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs752628575, COSV56913428; called by muse, mutect2, varscan2
- EYA2 | c.433C>T p.Q145* | Nonsense Mutation (SNP) | VAF 284/421 reads (67%) | catalogued as rs867149574, COSV100427086; called by muse, mutect2, varscan2
- FAAH | c.103_133del p.R35Dfs*31 | Frame Shift Del (DEL) | VAF 292/656 reads (45%) | catalogued as rs749442351; called by mutect2, varscan2
- FAM135B | c.2587C>T p.P863S | Missense Mutation (SNP) | VAF 197/313 reads (63%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs1563691297, COSV52715866; called by muse, mutect2, varscan2
- FAM135B | c.2521G>A p.G841S | Missense Mutation (SNP) | VAF 224/390 reads (57%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as rs1319014818; called by muse, mutect2
- FAM167A | c.101C>T p.T34I | Missense Mutation (SNP) | VAF 506/507 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as COSV99461298; called by muse, mutect2, varscan2
- FAM181A | c.442G>A p.D148N | Missense Mutation (SNP) | VAF 206/419 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.087); catalogued as rs1210196399, COSV50888079, COSV99967891; called by muse, mutect2, varscan2
- FAM227A | c.688C>T p.R230C | Missense Mutation (SNP) | VAF 311/311 reads (100%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs1452427974, COSV100874750; called by muse, mutect2, varscan2
- FAM3D | c.526C>T p.R176W | Missense Mutation (SNP) | VAF 168/351 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs368657516, COSV62558505; called by muse, mutect2, varscan2
- FAM83C | c.976C>T p.P326S | Missense Mutation (SNP) | VAF 239/715 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as rs548637692; called by muse, mutect2, varscan2
- FAN1 | c.518A>G p.D173G | Missense Mutation (SNP) | VAF 82/201 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs1023630555; called by muse, mutect2, varscan2
- FAT1 | c.2192C>A p.P731H | Missense Mutation (SNP) | VAF 322/322 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV101499434; called by muse, mutect2, varscan2
- FAT3 | c.4199G>A p.G1400E | Missense Mutation (SNP) | VAF 116/198 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53111792; called by muse, mutect2, varscan2
- FATE1 | c.127C>T p.R43W | Missense Mutation (SNP) | VAF 161/161 reads (100%) | SIFT tolerated (0.16); PolyPhen benign (0.013); catalogued as rs1411504856, COSV64849214; called by muse, mutect2, varscan2
- FBH1 | c.1591C>T p.L531F (on ENST00000362091 / NM_178150.3; = p.L582F on NM_032807.4) | Missense Mutation (SNP) | VAF 163/273 reads (60%) | SIFT tolerated (0.93); PolyPhen benign (0.003); catalogued as rs1300202340, COSV62984667; called by muse, mutect2, varscan2
- FBRSL1 | c.2725C>T p.P909S | Missense Mutation (SNP) | VAF 175/443 reads (40%) | SIFT tolerated (0.5); PolyPhen benign (0.009); catalogued as rs893215127; called by muse, mutect2, varscan2
- FBXW7 | c.1408C>T p.H470Y (on ENST00000281708 / NM_001349798.2; = p.H390Y on NM_018315.5) | Missense Mutation (SNP) | VAF 117/117 reads (100%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.837); catalogued as rs1169241042, COSV55911610; called by muse, mutect2, varscan2
- FCRL5 | c.1844G>A p.G615E | Missense Mutation (SNP) | VAF 294/296 reads (99%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as COSV100708668; called by muse, mutect2, varscan2
- FDXR | c.844C>T p.R282* (on ENST00000293195 / NM_024417.5; = p.R288* on NM_004110.6) | Nonsense Mutation (SNP) | VAF 448/1402 reads (32%) | catalogued as rs760046738, COSV53110797; called by muse, varscan2
- FGFR1 | c.1333C>T p.R445W (on ENST00000447712 / NM_023110.3; = p.R443W on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 206/206 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781608303, COSV58330773; called by muse, mutect2, varscan2
- FHL5 | c.578G>A p.R193K | Missense Mutation (SNP) | VAF 284/286 reads (99%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV58736915; called by muse, mutect2, varscan2
- FKBP8 | c.341C>T p.S114L | Missense Mutation (SNP) | VAF 421/623 reads (68%) | SIFT tolerated (0.3); PolyPhen benign (0.04); catalogued as rs756695076, COSV55892169; called by muse, mutect2, varscan2
- FOSB | c.896C>T p.S299L | Missense Mutation (SNP) | VAF 244/681 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs879647443, COSV62278737; called by muse, mutect2, varscan2
- FOXP2 | c.1295C>A p.S432* | Nonsense Mutation (SNP) | VAF 105/185 reads (57%) | catalogued as COSV100646263, COSV100646655; called by muse, mutect2, varscan2
- FREM3 | c.6206G>A p.R2069Q | Missense Mutation (SNP) | VAF 186/188 reads (99%) | SIFT tolerated (0.23); PolyPhen benign (0.104); catalogued as rs575349973, COSV61680487; called by muse, mutect2, varscan2
- GABRA2 | c.1067A>G p.E356G | Missense Mutation (SNP) | VAF 166/166 reads (100%) | SIFT tolerated (0.15); PolyPhen benign (0.428); catalogued as rs770470348; called by muse, mutect2, varscan2
- GABRA2 | c.677G>A p.G226E | Missense Mutation (SNP) | VAF 188/191 reads (98%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100734259; called by muse, mutect2, varscan2
- GABRA6 | c.496G>A p.D166N | Missense Mutation (SNP) | VAF 76/294 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50878989, COSV50879242; called by muse, mutect2, varscan2
- GALNT13 | c.26T>G p.V9G | Missense Mutation (SNP) | VAF 154/276 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as COSV101222327; called by muse, mutect2, varscan2
- GALNT15 | c.1277C>T p.S426F | Missense Mutation (SNP) | VAF 138/302 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs375198104; called by muse, mutect2
- GALNT17 | c.1033C>T p.P345S | Missense Mutation (SNP) | VAF 62/172 reads (36%) | SIFT tolerated (0.41); PolyPhen benign (0.022); catalogued as rs751577191, COSV61164917; called by muse, mutect2, varscan2
- GALNT17 | c.1034C>T p.P345L | Missense Mutation (SNP) | VAF 62/172 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.024); catalogued as COSV100353875; called by muse, mutect2, varscan2
- GATD1 | c.527C>T p.S176L | Missense Mutation (SNP) | VAF 206/426 reads (48%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs766317610, COSV60592311; called by muse, mutect2, varscan2
- GCN1 | c.4649C>T p.S1550F | Missense Mutation (SNP) | VAF 167/416 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56113660; called by muse, mutect2, varscan2
- GIMAP1 | c.337C>T p.H113Y | Missense Mutation (SNP) | VAF 180/435 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs75828764, COSV56187966; called by muse, mutect2, varscan2
- GIMAP8 | c.1607G>A p.R536Q | Missense Mutation (SNP) | VAF 155/355 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.371); catalogued as rs1338376937, COSV100217367, COSV56230030; called by muse, mutect2, varscan2
- GLI2 | c.3448C>T p.P1150S (on ENST00000361492 / NM_001374353.1; = p.P1167S on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 344/511 reads (67%) | SIFT tolerated (0.42); PolyPhen benign (0.013); catalogued as COSV100082691; called by muse, mutect2, varscan2
- GLIPR1L1 | c.524G>A p.G175E | Missense Mutation (SNP) | VAF 69/116 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1161016551; called by muse, mutect2, varscan2
- GNL2 | c.1018C>T p.P340S | Missense Mutation (SNP) | VAF 56/239 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.591); catalogued as rs368064874; called by muse, mutect2, varscan2
- GORASP2 | c.985C>T p.P329S | Missense Mutation (SNP) | VAF 109/356 reads (31%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); catalogued as COSV52203578; called by muse, mutect2, varscan2
- GPANK1 | c.941C>T p.T314I | Missense Mutation (SNP) | VAF 971/973 reads (100%) | SIFT tolerated (0.18); PolyPhen benign (0.039); catalogued as COSV63264286; called by muse, mutect2, varscan2
- GPATCH3 | c.683C>T p.S228F | Missense Mutation (SNP) | VAF 190/594 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs868189049; called by muse, varscan2
- GPR149 | c.2173G>A p.E725K | Missense Mutation (SNP) | VAF 128/217 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as rs1290725918, COSV67668137; called by muse, mutect2, varscan2
- GPR149 | c.688C>T p.Q230* | Nonsense Mutation (SNP) | VAF 158/578 reads (27%) | catalogued as rs776145796; called by muse, mutect2, varscan2
- GPR15 | c.569C>T p.P190L | Missense Mutation (SNP) | VAF 143/316 reads (45%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV52521815; called by muse, mutect2, varscan2
- GPR162 | c.1469C>T p.S490L (on ENST00000311268 / NM_019858.2; = p.S206L on NM_014449.2) | Missense Mutation (SNP) | VAF 215/561 reads (38%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.012); catalogued as rs1555120303, COSV51834149; called by muse, mutect2, varscan2
- GRB7 | c.1054C>T p.R352C | Missense Mutation (SNP) | VAF 49/198 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs750966050, COSV58450074; called by muse, mutect2, varscan2
- GRID2 | c.311C>T p.S104F | Missense Mutation (SNP) | VAF 298/298 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as rs574540768, COSV56253969, COSV56265711; called by muse, mutect2, varscan2
- GRIK3 | c.2624G>A p.R875Q | Missense Mutation (SNP) | VAF 149/415 reads (36%) | SIFT tolerated (0.29); PolyPhen benign (0.173); catalogued as rs765733567, COSV66136946, COSV66145394; called by muse, mutect2, varscan2
- GRIN3B | c.1681G>A p.D561N | Missense Mutation (SNP) | VAF 434/629 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99312908; called by muse, mutect2, varscan2
- GRIP2 | c.334G>A p.D112N (on ENST00000619221; = p.D15N on NM_001080423.4) | Missense Mutation (SNP) | VAF 122/248 reads (49%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.12); catalogued as rs375242872; called by muse, mutect2, varscan2
- GRM7 | c.1009C>T p.Q337* | Nonsense Mutation (SNP) | VAF 99/207 reads (48%) | catalogued as COSV63159961; called by muse, mutect2, varscan2
- GRM7 | c.1202A>C p.N401T | Missense Mutation (SNP) | VAF 97/201 reads (48%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV100736334; called by muse, mutect2, varscan2
- HABP2 | c.574G>A p.D192N | Missense Mutation (SNP) | VAF 79/148 reads (53%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as rs768881945; called by muse, mutect2, varscan2
- HBE1 | c.212C>T p.S71F | Missense Mutation (SNP) | VAF 88/186 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV53079530; called by muse, varscan2
- HBE1 | c.122G>A p.R41K | Missense Mutation (SNP) | VAF 66/134 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.238); catalogued as rs143266716, COSV99496377; called by muse, varscan2
- HDC | c.1672C>T p.P558S | Missense Mutation (SNP) | VAF 234/470 reads (50%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); catalogued as COSV99984198; called by muse, mutect2
- HECTD1 | c.1444C>T p.P482S | Missense Mutation (SNP) | VAF 102/174 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV67948993; called by muse, mutect2, varscan2
- HECTD4 | c.9227C>T p.P3076L | Missense Mutation (SNP) | VAF 246/446 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs771593426; called by muse, mutect2, varscan2
- HECTD4 | c.7114C>T p.R2372* | Nonsense Mutation (SNP) | VAF 235/400 reads (59%) | catalogued as COSV66389683; called by muse, mutect2, varscan2
- HEPHL1 | c.527C>T p.P176L | Missense Mutation (SNP) | VAF 210/381 reads (55%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as rs749893723; called by muse, mutect2, varscan2
- HNF4G | c.281G>A p.S94N (on ENST00000354370 / NM_001330561.2; = p.S141N on NM_004133.5) | Missense Mutation (SNP) | VAF 84/275 reads (31%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs374852729; called by muse, mutect2, varscan2
- HNF4G | c.1039G>A p.D347N (on ENST00000354370 / NM_001330561.2; = p.D394N on NM_004133.5) | Missense Mutation (SNP) | VAF 129/211 reads (61%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.597); catalogued as rs1364007068; called by muse, mutect2, varscan2
- HS2ST1 | c.634G>A p.E212K | Missense Mutation (SNP) | VAF 245/245 reads (100%) | SIFT tolerated (0.52); PolyPhen benign (0.03); catalogued as COSV63351043; called by muse, mutect2, varscan2
- HS3ST6 | c.490C>G p.P164A | Missense Mutation (SNP) | VAF 288/631 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV53534660; called by muse, mutect2, varscan2
- HSD3B2 | c.931C>T p.Q311* | Nonsense Mutation (SNP) | VAF 317/479 reads (66%) | catalogued as rs781213951; called by muse, mutect2, varscan2
- HTR2C | c.1273G>A p.E425K | Missense Mutation (SNP) | VAF 268/269 reads (100%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs781872799, COSV52221051, COSV52226263; called by muse, mutect2, varscan2
- HTR4 | c.320C>T p.S107L | Missense Mutation (SNP) | VAF 284/423 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779822851, COSV58789696; called by muse, mutect2, varscan2
- HYDIN | c.12482G>A p.G4161E | Missense Mutation (SNP) | VAF 147/152 reads (97%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV66638025; called by muse, mutect2, varscan2
- HYDIN | c.7669G>A p.E2557K | Missense Mutation (SNP) | VAF 350/351 reads (100%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.994); catalogued as rs267604619, COSV59263830; called by muse, mutect2, varscan2
- IL18BP | c.158C>T p.S53F | Missense Mutation (SNP) | VAF 273/447 reads (61%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.007); catalogued as COSV52622654; called by muse, mutect2, varscan2
- IMPG1 | c.805C>T p.Q269* | Nonsense Mutation (SNP) | VAF 243/243 reads (100%) | catalogued as rs779243802; called by muse, mutect2, varscan2
- ITGA2B | c.866C>T p.P289L | Missense Mutation (SNP) | VAF 125/423 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.216); catalogued as rs1310216248; called by muse, mutect2, varscan2
- ITGA2B | c.865C>T p.P289S | Missense Mutation (SNP) | VAF 124/421 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as rs370889770; called by muse, mutect2, varscan2
- ITGAV | c.644C>T p.S215L | Missense Mutation (SNP) | VAF 94/148 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as rs761237786, COSV99655302; called by muse, mutect2, varscan2
- ITIH1 | c.160C>T p.R54W | Missense Mutation (SNP) | VAF 105/210 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as rs369758909; called by muse, mutect2, varscan2
- ITPRID1 | c.1049C>T p.S350F | Missense Mutation (SNP) | VAF 105/209 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.15); catalogued as rs868170414; called by muse, mutect2, varscan2
- KAT6A | c.209C>T p.S70F | Missense Mutation (SNP) | VAF 73/73 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55904881; called by muse, mutect2, varscan2
- KCNH5 | c.1439G>A p.R480Q | Missense Mutation (SNP) | VAF 89/244 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs567491628, COSV59751574; called by muse, mutect2, varscan2
- KCNMB2 | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 94/293 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.932); catalogued as COSV64200463; called by muse, mutect2, varscan2
- KCNQ2 | c.1571C>T p.P524L (on ENST00000359125 / NM_172107.4; = p.P496L on NM_004518.6) | Missense Mutation (SNP) | VAF 152/530 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.09); catalogued as COSV60541360; called by muse, mutect2, varscan2
- KCP | c.3877G>A p.D1293N (on ENST00000620378; = p.D1417N on NM_001366122.1) | Missense Mutation (SNP) | VAF 179/386 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1411134993; called by muse, mutect2, varscan2
- KDM4C | c.2336C>T p.A779V | Missense Mutation (SNP) | VAF 155/155 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771913571; called by muse, mutect2, varscan2
- KIAA1549 | c.1385C>T p.S462F | Missense Mutation (SNP) | VAF 156/310 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs748604284; called by muse, mutect2, varscan2
- KIF2B | c.1399G>A p.E467K | Missense Mutation (SNP) | VAF 146/447 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52128836, COSV99276329; called by muse, mutect2, varscan2
- KIF4B | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 356/546 reads (65%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.588); catalogued as rs1390704156, COSV70530133; called by muse, varscan2
- KLHDC7A | c.1378G>A p.E460K | Missense Mutation (SNP) | VAF 200/635 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.095); catalogued as rs780616009, COSV68769217; called by muse, mutect2, varscan2
- KMT2C | c.8252C>T p.S2751L | Missense Mutation (SNP) | VAF 61/140 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV51486822; called by muse, mutect2, varscan2
- KNSTRN | c.61G>A p.E21K | Missense Mutation (SNP) | VAF 117/285 reads (41%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); catalogued as COSV51104185; called by muse, mutect2, varscan2
- KREMEN1 | c.1304G>A p.G435E (on ENST00000407188; = p.G437E on NM_032045.5) | Missense Mutation (SNP) | VAF 110/322 reads (34%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.784); catalogued as rs780288229; called by muse, mutect2, varscan2
- KRT9 | c.1348G>A p.E450K | Missense Mutation (SNP) | VAF 103/324 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55854363; called by muse, mutect2, varscan2
- KRTAP16-1 | c.1487C>T p.P496L | Missense Mutation (SNP) | VAF 195/1073 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.43); catalogued as rs1244236335; called by muse, mutect2, varscan2
- LAMP5 | c.337C>T p.R113C | Missense Mutation (SNP) | VAF 197/345 reads (57%) | SIFT deleterious (0.02); PolyPhen benign (0.417); catalogued as COSV55717004, COSV99855551; called by muse, mutect2, varscan2
- LPIN1 | c.2320A>G p.K774E | Missense Mutation (SNP) | VAF 53/239 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.029); catalogued as rs746241107; called by muse, mutect2, varscan2
- LRP1B | c.6532G>A p.D2178N | Missense Mutation (SNP) | VAF 175/269 reads (65%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV101257510, COSV67270444; called by muse, mutect2, varscan2
- LRP1B | c.4974G>A p.W1658* | Nonsense Mutation (SNP) | VAF 70/277 reads (25%) | catalogued as COSV101259979; called by muse, mutect2, varscan2
- LRRC32 | c.209G>C p.G70A | Missense Mutation (SNP) | VAF 268/486 reads (55%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as COSV52632151; called by muse, varscan2
- LRRC32 | c.208G>T p.G70C | Missense Mutation (SNP) | VAF 267/487 reads (55%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.649); catalogued as COSV52634524; called by muse, varscan2
- LRRC37A3 | c.3655A>G p.T1219A | Missense Mutation (SNP) | VAF 207/954 reads (22%) | SIFT tolerated (0.71); PolyPhen benign (0.037); catalogued as rs769655559; called by muse, mutect2, varscan2
- LRRC37A3 | c.157C>T p.P53S | Missense Mutation (SNP) | VAF 120/1015 reads (12%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.684); catalogued as rs753163489; called by muse, mutect2, varscan2
- LRRC42 | c.55C>T p.R19* | Nonsense Mutation (SNP) | VAF 295/429 reads (69%) | catalogued as rs548977787, COSV59961212; called by muse, mutect2, varscan2
- LRRCC1 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 62/96 reads (65%) | SIFT deleterious (0); PolyPhen benign (0.282); catalogued as COSV64482985; called by muse, mutect2, varscan2
- LRRTM4 | c.1232C>T p.P411L | Missense Mutation (SNP) | VAF 115/424 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV69142712; called by muse, mutect2, varscan2
- LTBP2 | c.2320C>T p.R774W | Missense Mutation (SNP) | VAF 227/502 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as rs763665239, COSV100001208; called by muse, mutect2, varscan2
- LY75 | c.1635G>A p.M545I | Missense Mutation (SNP) | VAF 56/165 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99716965; called by muse, mutect2, varscan2
- LYST | c.1267C>T p.P423S | Missense Mutation (SNP) | VAF 320/321 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1473462652; called by muse, mutect2, varscan2
- MACF1 | c.10705C>T p.R3569* | Nonsense Mutation (SNP) | VAF 114/379 reads (30%) | catalogued as rs1304702741, COSV57143322; called by muse, mutect2, varscan2
- MAGEC1 | c.1864C>T p.Q622* | Nonsense Mutation (SNP) | VAF 436/438 reads (100%) | catalogued as rs993628156; called by muse, varscan2
- MAGEC2 | c.97G>A p.D33N | Missense Mutation (SNP) | VAF 443/443 reads (100%) | SIFT tolerated (0.55); PolyPhen benign (0.137); catalogued as rs1159409994; called by muse, mutect2, varscan2
- MALRD1 | c.4467A>T p.E1489D | Missense Mutation (SNP) | VAF 56/128 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.546); catalogued as COSV65990102; called by muse, mutect2, varscan2
- MAP3K1 | c.2122G>A p.E708K | Missense Mutation (SNP) | VAF 167/168 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99063948; called by muse, mutect2, varscan2
- MAP3K2 | c.322C>G p.R108G | Missense Mutation (SNP) | VAF 66/146 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.877); catalogued as rs1179996329; called by muse, varscan2
- MAP4K2 | c.2300G>A p.R767Q | Missense Mutation (SNP) | VAF 230/364 reads (63%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.604); catalogued as rs935494939; called by muse, mutect2, varscan2
- MBL2 | c.358G>A p.A120T | Missense Mutation (SNP) | VAF 138/241 reads (57%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as rs769868112, COSV64759182; called by muse, mutect2, varscan2
- MCF2 | c.1640G>A p.G547E | Missense Mutation (SNP) | VAF 25/121 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100644627; called by muse, mutect2, varscan2
- MDH1B | c.520G>A p.E174K | Missense Mutation (SNP) | VAF 111/355 reads (31%) | SIFT tolerated (0.39); PolyPhen benign (0.012); catalogued as COSV100982150; called by muse, mutect2, varscan2
- ME2 | c.407C>T p.S136L | Missense Mutation (SNP) | VAF 99/102 reads (97%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as rs1383727648; called by muse, mutect2, varscan2
- MECOM | c.1807C>T p.P603S (on ENST00000468789 / NM_001105078.4; = p.P791S on NM_004991.4) | Missense Mutation (SNP) | VAF 322/511 reads (63%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV52972121; called by muse, mutect2, varscan2
- MED25 | c.2080C>T p.P694S | Missense Mutation (SNP) | VAF 556/557 reads (100%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0.057); catalogued as rs968448750; called by muse, mutect2, varscan2
- MED25 | c.2081C>T p.P694L | Missense Mutation (SNP) | VAF 551/551 reads (100%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); catalogued as rs756047976; called by muse, mutect2, varscan2
- MEGF8 | c.1228C>T p.R410W | Missense Mutation (SNP) | VAF 155/493 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs755656068; called by muse, mutect2, varscan2
- MEP1B | c.1919G>A p.G640E | Missense Mutation (SNP) | VAF 248/250 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1568274613; called by muse, mutect2, varscan2
- MGAM | c.2884G>A p.E962K | Missense Mutation (SNP) | VAF 64/145 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.726); catalogued as COSV101527511; called by mutect2, varscan2
- MGAM2 | c.1066C>T p.R356C | Missense Mutation (SNP) | VAF 44/137 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs867891460, COSV104438575; called by muse, mutect2, varscan2
- MGAT2 | c.1019C>T p.T340I | Missense Mutation (SNP) | VAF 187/326 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1165349794; called by muse, mutect2, varscan2
- MIB2 | c.367G>A p.G123S | Missense Mutation (SNP) | VAF 316/953 reads (33%) | SIFT tolerated (0.43); PolyPhen benign (0.136); catalogued as COSV61756622; called by muse, mutect2, varscan2
- MIP | c.658G>A p.D220N | Missense Mutation (SNP) | VAF 248/385 reads (64%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as rs1394124537, COSV57516313; called by muse, mutect2, varscan2
- MISP | c.1469G>A p.G490E | Missense Mutation (SNP) | VAF 475/672 reads (71%) | SIFT tolerated (0.26); PolyPhen benign (0.022); catalogued as COSV53122032; called by muse, mutect2, varscan2
- MLF1 | c.160C>G p.R54G | Missense Mutation (SNP) | VAF 153/249 reads (61%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.655); catalogued as COSV63034754; called by muse, mutect2, varscan2
- MLLT1 | c.782C>T p.T261I | Missense Mutation (SNP) | VAF 306/484 reads (63%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.852); catalogued as rs1220387347; called by muse, mutect2, varscan2
- MROH7 | c.3178G>A p.E1060K | Missense Mutation (SNP) | VAF 372/540 reads (69%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.981); catalogued as COSV59870895; called by muse, mutect2, varscan2
- MSH6 | c.1259A>T p.N420I | Missense Mutation (SNP) | VAF 292/484 reads (60%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.864); catalogued as rs1363957491; called by muse, mutect2
- MSH6 | c.1943G>A p.S648N | Missense Mutation (SNP) | VAF 167/499 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as CD105408; called by muse, mutect2, varscan2
- MST1R | c.1722C>T p.F574= | Splice Region (SNP) | VAF 109/242 reads (45%) | catalogued as COSV56567044; called by muse, mutect2, varscan2
- MUC16 | c.34336G>A p.A11446T | Missense Mutation (SNP) | VAF 84/305 reads (28%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.093); catalogued as rs376027119; called by muse, mutect2, varscan2
- MUC16 | c.32468C>T p.S10823L | Missense Mutation (SNP) | VAF 112/412 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.162); catalogued as rs267605785, COSV67454184; called by muse, mutect2, varscan2
- MUC16 | c.30742G>A p.E10248K | Missense Mutation (SNP) | VAF 94/324 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.547); catalogued as COSV104431823, COSV67455036; called by muse, mutect2, varscan2
- MUC16 | c.21199C>T p.P7067S | Missense Mutation (SNP) | VAF 130/445 reads (29%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.393); catalogued as rs1403709235, COSV67481945; called by muse, mutect2, varscan2
- MUC17 | c.50C>T p.S17L | Missense Mutation (SNP) | VAF 155/339 reads (46%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.067); catalogued as rs143525513, COSV100074956; called by muse, mutect2, varscan2
- MUC22 | c.3005C>T p.S1002F | Missense Mutation (SNP) | VAF 672/679 reads (99%) | SIFT deleterious (0); catalogued as rs1475976856; called by muse, mutect2, varscan2
- MXRA5 | c.4210C>T p.L1404F | Missense Mutation (SNP) | VAF 163/163 reads (100%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV54252336; called by muse, mutect2, varscan2
- MXRA5 | c.2653G>A p.E885K | Missense Mutation (SNP) | VAF 175/176 reads (99%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV54233633; called by muse, mutect2, varscan2
- MYH1 | c.3379G>A p.E1127K | Missense Mutation (SNP) | VAF 246/249 reads (99%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as rs775607124, COSV56848838; called by muse, mutect2, varscan2
- MYH8 | c.4624G>A p.E1542K | Missense Mutation (SNP) | VAF 55/55 reads (100%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.895); catalogued as rs868298868, COSV67968661; called by muse, mutect2, varscan2
- MYO18B | c.1090G>A p.E364K | Missense Mutation (SNP) | VAF 608/611 reads (100%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1401947638, COSV59144930; called by muse, mutect2, varscan2
- MYO1G | c.2653C>T p.R885W | Missense Mutation (SNP) | VAF 142/322 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs1486210938, COSV51857288; called by muse, mutect2, varscan2
- MYO7A | c.904C>T p.R302C | Missense Mutation (SNP) | VAF 109/331 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs781922871, COSV68685692; ClinVar: likely benign; called by muse, mutect2, varscan2
- MYO7A | c.1531G>A p.D511N | Missense Mutation (SNP) | VAF 168/279 reads (60%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV68684526, COSV68686937; called by muse, varscan2
- MYO9A | c.3877C>T p.R1293C | Missense Mutation (SNP) | VAF 103/269 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1307006954, COSV61848277; called by muse, mutect2, varscan2
- NDN | c.101C>T p.P34L | Missense Mutation (SNP) | VAF 177/395 reads (45%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV100086429, COSV59359532; called by muse, mutect2, varscan2
- NEUROD4 | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 137/381 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as rs1419032933, COSV54471844; called by muse, mutect2, varscan2
- NF2 | c.970C>T p.Q324* | Nonsense Mutation (SNP) | VAF 212/212 reads (100%) | catalogued as rs74315500, CM070209, COSV58522318; called by muse, mutect2, varscan2
- NFE2L2 | c.847G>A p.D283N | Missense Mutation (SNP) | VAF 295/499 reads (59%) | SIFT tolerated (0.13); PolyPhen benign (0.205); catalogued as COSV67960158; called by muse, mutect2, varscan2
- NFKBIZ | c.869C>T p.S290F | Missense Mutation (SNP) | VAF 138/459 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as rs774349082, COSV58201948; called by muse, mutect2, varscan2
- NGB | c.314C>T p.S105F | Missense Mutation (SNP) | VAF 126/237 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV53611126; called by muse, mutect2, varscan2
- NGFR | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 90/294 reads (31%) | SIFT tolerated (0.89); PolyPhen benign (0.282); catalogued as rs1479874707; called by muse, mutect2, varscan2
- NLRC3 | c.2206G>A p.D736N | Missense Mutation (SNP) | VAF 294/536 reads (55%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.969); catalogued as rs774771502, COSV57093015; called by muse, mutect2, varscan2
- NLRP4 | c.99G>A p.M33I | Missense Mutation (SNP) | VAF 204/206 reads (99%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs1482269613; called by muse, mutect2, varscan2
- NLRP5 | c.2522C>T p.S841F | Missense Mutation (SNP) | VAF 268/268 reads (100%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs1220164982, COSV101173564; called by muse, mutect2, varscan2
- NLRP8 | c.2881G>A p.E961K | Missense Mutation (SNP) | VAF 184/184 reads (100%) | SIFT tolerated (0.38); PolyPhen benign (0.274); catalogued as rs761831926, COSV52583592, COSV52587481; called by muse, mutect2, varscan2
- NLRP9 | c.1660G>A p.E554K | Missense Mutation (SNP) | VAF 153/154 reads (99%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.542); catalogued as COSV60463477; called by muse, mutect2, varscan2
- NOL4 | c.1141G>A p.G381R | Missense Mutation (SNP) | VAF 241/241 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV52345033; called by muse, mutect2, varscan2
- NOTCH4 | c.4117G>A p.E1373K | Missense Mutation (SNP) | VAF 619/620 reads (100%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs919103129, COSV66683856; called by muse, mutect2, varscan2
- NOTCH4 | c.254C>T p.P85L | Missense Mutation (SNP) | VAF 887/888 reads (100%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as rs773859864; called by muse, mutect2, varscan2
- NT5C1B | c.485G>A p.S162N (on ENST00000359846 / NM_001199086.2; = p.S102N on NM_033253.4) | Missense Mutation (SNP) | VAF 186/568 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as rs757813091; called by muse, mutect2, varscan2
- NUP210L | c.3383G>A p.R1128K | Missense Mutation (SNP) | VAF 396/398 reads (99%) | SIFT tolerated (0.82); PolyPhen possibly damaging (0.527); catalogued as rs759030187; called by muse, mutect2, varscan2
- OASL | c.1198C>T p.P400S | Missense Mutation (SNP) | VAF 177/442 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.454); catalogued as rs1408905535; called by muse, mutect2, varscan2
- OBSCN | c.18778G>A p.G6260R | Missense Mutation (SNP) | VAF 666/670 reads (99%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs1453931044, COSV52812991; called by muse, mutect2
- OBSCN | c.18779G>A p.G6260E | Missense Mutation (SNP) | VAF 661/666 reads (99%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs1311894435; called by muse, mutect2
- OR10A3 | c.149C>T p.S50F | Missense Mutation (SNP) | VAF 146/334 reads (44%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as rs866622532, COSV62459092; called by muse, mutect2, varscan2
- OR11G2 | c.824C>T p.A275V | Missense Mutation (SNP) | VAF 256/372 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs756487616; called by muse, mutect2, varscan2
- OR11H1 | c.748G>A p.A250T | Missense Mutation (SNP) | VAF 289/318 reads (91%) | SIFT tolerated (0.24); PolyPhen benign (0.417); catalogued as rs1434899930; called by muse, mutect2, varscan2
- OR2L5 | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 210/211 reads (100%) | SIFT deleterious (0.01); PolyPhen benign (0.067); catalogued as rs566745463; called by muse, mutect2, varscan2
- OR3A3 | c.712C>T p.R238C | Missense Mutation (SNP) | VAF 273/273 reads (100%) | SIFT tolerated (0.07); PolyPhen benign (0.047); catalogued as rs762561652, COSV52168001, COSV52168316; called by muse, mutect2, varscan2
- OR4A47 | c.266C>T p.S89F | Missense Mutation (SNP) | VAF 100/207 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.021); catalogued as rs759878805; called by muse, mutect2, varscan2
- OR4A5 | c.227C>T p.S76F | Missense Mutation (SNP) | VAF 98/217 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.03); catalogued as rs1287252869; called by muse, varscan2
- OR4Q3 | c.227C>T p.S76F | Missense Mutation (SNP) | VAF 48/211 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59180270; called by muse, mutect2, varscan2
- OR51B5 | c.317C>T p.S106F | Missense Mutation (SNP) | VAF 154/323 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs1435926857, COSV56175601; called by muse, mutect2, varscan2
- OR51F2 | c.857C>T p.P286L | Missense Mutation (SNP) | VAF 96/229 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs917687952; called by muse, mutect2, varscan2
- OR5P3 | c.415G>A p.G139R | Missense Mutation (SNP) | VAF 220/439 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs866957625; called by muse, mutect2, varscan2
- OR6S1 | c.638C>T p.S213F | Missense Mutation (SNP) | VAF 113/410 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs776108341; called by muse, mutect2, varscan2
- OR8U1 | c.475C>T p.H159Y | Missense Mutation (SNP) | VAF 110/232 reads (47%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.901); catalogued as COSV100163976, COSV56416047; called by muse, mutect2, varscan2
- OR9A2 | c.247G>A p.G83R | Missense Mutation (SNP) | VAF 184/338 reads (54%) | SIFT tolerated (0.06); PolyPhen benign (0.093); catalogued as COSV63306601; called by muse, mutect2, varscan2
- OTOF | c.1927G>A p.E643K | Missense Mutation (SNP) | VAF 259/378 reads (69%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as rs200864338, COSV55496524; called by muse, mutect2, varscan2
- OTOGL | c.2113G>A p.D705N (on ENST00000547103; = p.D696N on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 275/430 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs762900798; called by muse, mutect2, varscan2
- PABPC1 | c.1398G>A p.M466I | Missense Mutation (SNP) | VAF 118/198 reads (60%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs753637297; called by muse, varscan2
- PABPC3 | c.1285C>T p.P429S | Missense Mutation (SNP) | VAF 216/245 reads (88%) | SIFT deleterious (0.01); PolyPhen benign (0.291); catalogued as COSV55802618; called by muse, varscan2
- PAGE4 | c.266C>T p.P89L | Missense Mutation (SNP) | VAF 172/172 reads (100%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99489880, COSV99489885; called by muse, mutect2, varscan2
- PAPPA2 | c.824G>A p.R275H | Missense Mutation (SNP) | VAF 320/419 reads (76%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.98); catalogued as rs548559188, COSV62787700; called by muse, mutect2, varscan2
- PAPPA2 | c.4091G>A p.G1364D | Missense Mutation (SNP) | VAF 303/303 reads (100%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs768157918; called by muse, mutect2, varscan2
- PCDH15 | c.3406G>A p.D1136N | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1298520846, COSV57372502, COSV57380811, COSV57404150; called by muse, mutect2, varscan2
- PCDH15 | c.1015C>T p.H339Y | Missense Mutation (SNP) | VAF 47/153 reads (31%) | SIFT tolerated (0.48); PolyPhen benign (0.131); catalogued as rs1320862880; called by muse, mutect2, varscan2
- PCDH7 | c.1948G>T p.E650* | Nonsense Mutation (SNP) | VAF 126/270 reads (47%) | catalogued as COSV62338350; called by muse, mutect2, varscan2
- PCDHA2 | c.2072C>T p.A691V | Missense Mutation (SNP) | VAF 188/641 reads (29%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.005); catalogued as rs373020261; called by muse, mutect2, varscan2
- PCDHB11 | c.928G>A p.E310K | Missense Mutation (SNP) | VAF 118/176 reads (67%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV61313910; called by muse, mutect2, varscan2
- PCDHB15 | c.1808C>T p.S603L | Missense Mutation (SNP) | VAF 364/760 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as rs1554292207, COSV99179319; called by muse, mutect2, varscan2
- PCDHGA3 | c.574C>T p.P192S | Missense Mutation (SNP) | VAF 319/488 reads (65%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.411); catalogued as COSV99532470; called by muse, mutect2, varscan2
- PCDHGA4 | c.1409C>T p.S470L | Missense Mutation (SNP) | VAF 149/470 reads (32%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.017); catalogued as COSV53921844; called by muse, mutect2, varscan2
- PCDHGA5 | c.1738C>T p.R580C | Missense Mutation (SNP) | VAF 168/584 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV54011405; called by muse, mutect2, varscan2
- PCDHGA5 | c.1819C>T p.R607C | Missense Mutation (SNP) | VAF 162/644 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.22); catalogued as rs532159175, COSV99546391; called by muse, mutect2, varscan2
- PCDHGB1 | c.2026G>A p.E676K | Missense Mutation (SNP) | VAF 179/595 reads (30%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as COSV53932117; called by muse, mutect2, varscan2
- PCLO | c.2945C>T p.S982F | Missense Mutation (SNP) | VAF 128/263 reads (49%) | SIFT tolerated (0.17); PolyPhen benign (0.116); catalogued as COSV61661666; called by muse, mutect2, varscan2
- PCNT | c.1034C>T p.T345I | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.025); catalogued as rs991004720; called by muse, mutect2, varscan2
- PCNT | c.1035C>T p.T345= | Splice Region (SNP) | VAF 34/87 reads (39%) | catalogued as rs771472003; called by muse, mutect2, varscan2
- PCSK6 | c.587G>A p.G196E | Missense Mutation (SNP) | VAF 296/298 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59339288; called by muse, mutect2, varscan2
- PENK | c.626G>A p.R209Q | Missense Mutation (SNP) | VAF 288/454 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs573652413, COSV59240213, COSV59242061; called by muse, mutect2, varscan2
- PGAP3 | c.332C>T p.S111L | Missense Mutation (SNP) | VAF 391/584 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765176692, COSV100328629; called by muse, mutect2, varscan2
- PIK3C2G | c.2335C>T p.R779C (on ENST00000676171; = p.R738C on NM_004570.5) | Missense Mutation (SNP) | VAF 30/148 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759658584, COSV56799291; called by muse, mutect2, varscan2
- PKDCC | c.1178G>A p.R393Q | Missense Mutation (SNP) | VAF 146/419 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.019); catalogued as rs374556546; called by muse, mutect2, varscan2
- PLCB4 | c.3116G>A p.R1039Q | Missense Mutation (SNP) | VAF 194/341 reads (57%) | SIFT tolerated (0.32); PolyPhen benign (0.062); catalogued as rs150881165; called by muse, mutect2, varscan2
- PLCB4 | c.3462G>A p.A1154= (on ENST00000278655 / NM_182797.3; = p.E1167K on NM_000933.4 and 2 other RefSeq transcripts) | Splice Region (SNP) | VAF 92/227 reads (41%) | catalogued as rs761885301, COSV53800025; called by muse, mutect2, varscan2
- PLCE1 | c.856G>A p.D286N | Missense Mutation (SNP) | VAF 181/303 reads (60%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0); catalogued as COSV53351649; called by muse, mutect2, varscan2
- PLCE1 | c.3991G>A p.D1331N | Missense Mutation (SNP) | VAF 249/401 reads (62%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.852); catalogued as rs372685240; called by muse, mutect2, varscan2
- PLCL2 | c.1687G>A p.G563R (on ENST00000615277 / NM_001144382.2; = p.G437R on NM_015184.5) | Missense Mutation (SNP) | VAF 80/195 reads (41%) | SIFT tolerated (0.44); PolyPhen benign (0.073); catalogued as rs781184639; called by muse, mutect2, varscan2
- PLEKHG4B | c.224G>A p.R75Q (on ENST00000283426; = p.R431Q on NM_052909.5) | Missense Mutation (SNP) | VAF 425/428 reads (99%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs1360885910, COSV52044370; called by muse, mutect2, varscan2
- POF1B | c.1267G>A p.E423K | Missense Mutation (SNP) | VAF 70/70 reads (100%) | SIFT deleterious (0.02); PolyPhen benign (0.168); catalogued as COSV99426850; called by muse, mutect2, varscan2
- POF1B | c.1120G>A p.E374K | Missense Mutation (SNP) | VAF 69/69 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs146172066, COSV99427068; called by muse, mutect2, varscan2
- POF1B | c.430C>T p.P144S | Missense Mutation (SNP) | VAF 19/19 reads (100%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.144); catalogued as COSV99427672; called by muse, mutect2, varscan2
- POLM | c.1282C>T p.P428S | Missense Mutation (SNP) | VAF 173/366 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0.086); catalogued as COSV54242663; called by muse, varscan2
- POTEI | c.2449G>A p.E817K | Missense Mutation (SNP) | VAF 120/480 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.736); catalogued as rs760790422, COSV71576077; called by muse, mutect2, varscan2
- PPP4R4 | c.272G>A p.R91Q | Missense Mutation (SNP) | VAF 101/231 reads (44%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.632); catalogued as rs201409663; called by muse, mutect2, varscan2
- PRR16 | c.604C>T p.R202* (on ENST00000407149 / NM_001300783.2; = p.R179* on NM_016644.2) | Nonsense Mutation (SNP) | VAF 282/447 reads (63%) | catalogued as rs1472141027, COSV101088537; called by muse, mutect2, varscan2
- PRUNE2 | c.5434G>A p.E1812K | Missense Mutation (SNP) | VAF 369/369 reads (100%) | SIFT tolerated (0.18); PolyPhen benign (0.017); catalogued as rs546778607, COSV65037525; called by muse, mutect2, varscan2
- PTGFRN | c.842C>T p.A281V | Missense Mutation (SNP) | VAF 170/246 reads (69%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs759360708; called by muse, mutect2, varscan2
- PTH2R | c.379C>T p.R127C | Missense Mutation (SNP) | VAF 116/198 reads (59%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.892); catalogued as rs373798724, COSV55914177; called by muse, mutect2, varscan2
- PTPDC1 | c.1582A>G p.K528E (on ENST00000375360 / NM_177995.3; = p.K580E on NM_152422.4) | Missense Mutation (SNP) | VAF 167/460 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1361964579; called by muse, mutect2, varscan2
- PTPN21 | c.2183C>T p.P728L | Missense Mutation (SNP) | VAF 234/481 reads (49%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.005); catalogued as rs750565186; called by muse, mutect2, varscan2
- PTPN21 | c.2182C>T p.P728S | Missense Mutation (SNP) | VAF 214/448 reads (48%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs1221405874; called by muse, varscan2
- PTPN7 | c.82G>A p.E28K (on ENST00000495688; = p.E67K on NM_002832.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 399/402 reads (99%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV58312284; called by muse, mutect2, varscan2
- PTPRB | c.125C>T p.S42F | Missense Mutation (SNP) | VAF 252/426 reads (59%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0.006); catalogued as COSV54246949; called by muse, mutect2, varscan2
- PTPRG | c.2351G>A p.G784E | Missense Mutation (SNP) | VAF 123/257 reads (48%) | SIFT tolerated (0.54); PolyPhen benign (0.024); catalogued as COSV55652767; called by muse, mutect2, varscan2
- PTPRT | c.4157G>A p.G1386E | Missense Mutation (SNP) | VAF 209/328 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1161104430; called by muse, mutect2, varscan2
- PTTG2 | c.239C>T p.P80L | Missense Mutation (SNP) | VAF 165/165 reads (100%) | SIFT tolerated (0.4); PolyPhen benign (0.057); catalogued as COSV99792048; called by muse, mutect2, varscan2
- PXDNL | c.2182C>T p.R728C | Missense Mutation (SNP) | VAF 183/564 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776364671, COSV62478863; called by muse, mutect2, varscan2
- RAPGEF5 | c.299C>T p.S100F | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as COSV99071009; called by muse, mutect2, varscan2
- RBM44 | c.448G>A p.E150K (on ENST00000611254; = p.E784K on NM_001080504.2) | Missense Mutation (SNP) | VAF 82/232 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.896); catalogued as rs200721449; called by muse, mutect2, varscan2
- RCC1 | c.269C>T p.S90F | Missense Mutation (SNP) | VAF 89/289 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); catalogued as COSV65779609; called by muse, mutect2, varscan2
- RELN | c.2368C>T p.Q790* | Nonsense Mutation (SNP) | VAF 92/221 reads (42%) | catalogued as COSV58995234; called by muse, mutect2, varscan2
- RELN | c.815C>T p.S272L | Missense Mutation (SNP) | VAF 79/168 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV59000510, COSV59036424; called by muse, mutect2, varscan2
- REST | c.1888C>T p.P630S | Missense Mutation (SNP) | VAF 352/352 reads (100%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.001); catalogued as rs958664617, COSV100470745; called by muse, mutect2, varscan2
- RGPD3 | c.4060G>A p.E1354K | Missense Mutation (SNP) | VAF 56/249 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769042286, COSV100450497; called by muse, mutect2
- RGPD8 | c.3017G>A p.R1006Q | Missense Mutation (SNP) | VAF 44/216 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs768082162; called by muse, mutect2, varscan2
- RGPD8 | c.637G>T p.E213* | Nonsense Mutation (SNP) | VAF 131/230 reads (57%) | catalogued as rs746453036; called by muse, mutect2, varscan2
- RGS11 | c.690C>T p.I230= (on ENST00000397770 / NM_183337.3; = p.I209= on NM_003834.3 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 301/668 reads (45%) | catalogued as rs762247831, COSV51451523; called by muse, mutect2, varscan2
- RHPN2 | c.343C>T p.L115F | Missense Mutation (SNP) | VAF 185/248 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV54276202; called by muse, varscan2
- RIPK2 | c.778C>T p.P260S | Missense Mutation (SNP) | VAF 131/233 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375657882; called by muse, mutect2, varscan2
- RIPOR3 | c.1766C>T p.S589F | Missense Mutation (SNP) | VAF 227/352 reads (64%) | SIFT deleterious (0); PolyPhen benign (0.203); catalogued as rs774417162; called by muse, mutect2, varscan2
- RNF17 | c.612G>A p.R204= | Splice Region (SNP) | VAF 17/17 reads (100%) | catalogued as COSV55037445; called by muse, mutect2, varscan2
- RP1 | c.1012C>T p.R338* | Nonsense Mutation (SNP) | VAF 45/123 reads (37%) | catalogued as CM130734, COSV55110264; called by muse, mutect2, varscan2
- RP1 | c.5859G>A p.M1953I | Missense Mutation (SNP) | VAF 103/168 reads (61%) | SIFT tolerated (0.07); PolyPhen benign (0.084); catalogued as COSV55115012; called by muse, mutect2, varscan2
- RPL10L | c.61C>T p.R21C | Missense Mutation (SNP) | VAF 245/375 reads (65%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs1264270481, COSV53558575; called by muse, mutect2, varscan2
- RPL26L1 | c.367G>A p.A123T | Missense Mutation (SNP) | VAF 14/370 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.045); catalogued as rs1037063908; called by muse, mutect2
- RPS6KA6 | c.1624C>T p.R542C | Missense Mutation (SNP) | VAF 88/88 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs139038048, COSV53123540; called by muse, mutect2, varscan2
- RTF1 | c.1061C>T p.S354F | Missense Mutation (SNP) | VAF 98/212 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV67479083; called by muse, mutect2, varscan2
- RTL4 | c.444G>A p.M148I | Missense Mutation (SNP) | VAF 178/179 reads (99%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV61206778; called by muse, mutect2, varscan2
- RYR1 | c.5692G>A p.E1898K | Missense Mutation (SNP) | VAF 407/1395 reads (29%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as COSV62114493; called by muse, mutect2, varscan2
- RYR2 | c.4252G>A p.D1418N | Missense Mutation (SNP) | VAF 218/218 reads (100%) | SIFT tolerated (0.11); PolyPhen benign (0.014); catalogued as COSV100770725; called by muse, mutect2, varscan2
- RYR2 | c.4421G>A p.G1474E | Missense Mutation (SNP) | VAF 172/172 reads (100%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.777); catalogued as COSV63668461, COSV63683480; called by muse, mutect2, varscan2
- RYR2 | c.12409G>A p.E4137K | Missense Mutation (SNP) | VAF 347/347 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs267598439, COSV63666259; called by muse, varscan2
- SBK2 | c.328G>A p.G110R | Missense Mutation (SNP) | VAF 420/420 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV60013648; called by muse, mutect2, varscan2
- SCARF1 | c.2467C>T p.P823S | Missense Mutation (SNP) | VAF 334/334 reads (100%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.051); catalogued as COSV99557252; called by muse, mutect2, varscan2
- SCARF2 | c.1922C>T p.A641V | Missense Mutation (SNP) | VAF 776/780 reads (99%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as rs984158225; called by muse, mutect2, varscan2
- SCN11A | c.5206G>A p.G1736S | Missense Mutation (SNP) | VAF 114/246 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs752885762; called by muse, mutect2, varscan2
- SCN7A | c.1786C>T p.R596* | Nonsense Mutation (SNP) | VAF 48/160 reads (30%) | catalogued as rs769655731, COSV69272846; called by muse, mutect2, varscan2
- SCN7A | c.1314G>A p.M438I | Missense Mutation (SNP) | VAF 96/174 reads (55%) | SIFT tolerated (0.48); PolyPhen benign (0.031); catalogued as rs868229903; called by muse, mutect2, varscan2
- SCPEP1 | c.163C>T p.L55F | Missense Mutation (SNP) | VAF 274/412 reads (67%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.889); catalogued as rs558517026; called by muse, mutect2, varscan2
- SDAD1 | c.1981C>T p.R661W | Missense Mutation (SNP) | VAF 71/72 reads (99%) | SIFT tolerated (0.05); PolyPhen benign (0.08); catalogued as rs202126090, COSV62402528; called by muse, mutect2, varscan2
- SDAD1 | c.232C>T p.P78S | Missense Mutation (SNP) | VAF 126/126 reads (100%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.989); catalogued as rs754724162, COSV62402389; called by muse, mutect2, varscan2
- SDSL | c.217G>A p.G73S | Missense Mutation (SNP) | VAF 180/285 reads (63%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); catalogued as rs1391527141; called by muse, mutect2, varscan2
- SEC61A2 | c.652C>T p.H218Y | Missense Mutation (SNP) | VAF 125/294 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.916); catalogued as COSV100036755; called by muse, mutect2, varscan2
- SELE | c.1642G>A p.E548K | Missense Mutation (SNP) | VAF 231/231 reads (100%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV60974761; called by muse, mutect2, varscan2
- SGMS1 | c.345G>A p.M115I | Missense Mutation (SNP) | VAF 218/371 reads (59%) | SIFT tolerated (0.45); PolyPhen benign (0.109); catalogued as COSV100693837; called by muse, mutect2, varscan2
- SGPP2 | c.649G>A p.D217N | Missense Mutation (SNP) | VAF 97/276 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs142560442; called by muse, mutect2, varscan2
- SHANK1 | c.4127C>T p.P1376L | Missense Mutation (SNP) | VAF 137/393 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.209); catalogued as rs1160385958; called by muse, mutect2, varscan2
- SI | c.4525G>A p.D1509N | Missense Mutation (SNP) | VAF 167/277 reads (60%) | SIFT tolerated (0.56); PolyPhen benign (0.288); catalogued as rs753423947; called by muse, mutect2, varscan2
- SI | c.748C>T p.R250C | Missense Mutation (SNP) | VAF 86/156 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs200745562, COSV52269530; ClinVar: uncertain significance; called by muse, mutect2
- SIGIRR | c.1003C>T p.R335* | Nonsense Mutation (SNP) | VAF 303/614 reads (49%) | catalogued as rs1042462889, COSV58987329; called by muse, mutect2, varscan2
- SIRPG | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 136/257 reads (53%) | SIFT tolerated (0.2); PolyPhen benign (0.047); catalogued as rs760442783; called by muse, mutect2, varscan2
- SIX4 | c.382C>T p.R128C | Missense Mutation (SNP) | VAF 349/593 reads (59%) | SIFT deleterious (0); PolyPhen benign (0.368); catalogued as rs776486708; called by muse, mutect2, varscan2
- SLC12A8 | c.1370A>G p.E457G | Missense Mutation (SNP) | VAF 180/483 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); catalogued as rs779967427; called by muse, mutect2, varscan2
- SLC15A2 | c.1133G>A p.R378K | Missense Mutation (SNP) | VAF 179/302 reads (59%) | SIFT tolerated (0.71); PolyPhen benign (0.123); catalogued as rs1361148386; called by muse, mutect2, varscan2
- SLC17A6 | c.1528G>A p.E510K | Missense Mutation (SNP) | VAF 121/235 reads (51%) | SIFT tolerated (0.28); PolyPhen benign (0.066); catalogued as COSV54137048; called by muse, mutect2, varscan2
- SLC17A7 | c.1625G>A p.G542E | Missense Mutation (SNP) | VAF 258/261 reads (99%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs770655435; called by muse, mutect2, varscan2
- SLC22A24 | c.1040G>A p.R347Q | Missense Mutation (SNP) | VAF 96/332 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as rs532105556, COSV101343507; called by muse, mutect2
- SLC22A8 | c.1522G>A p.E508K | Missense Mutation (SNP) | VAF 227/632 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.079); catalogued as rs1476631667; called by muse, mutect2, varscan2
- SLC24A2 | c.164C>T p.S55L | Missense Mutation (SNP) | VAF 238/238 reads (100%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV53869312; called by muse, mutect2, varscan2
- SLC2A12 | c.1238C>T p.S413F | Missense Mutation (SNP) | VAF 172/172 reads (100%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV51602052; called by muse, mutect2, varscan2
- SLC2A12 | c.808C>T p.R270C | Missense Mutation (SNP) | VAF 164/164 reads (100%) | SIFT deleterious (0.04); PolyPhen benign (0.127); catalogued as rs779184200, COSV51597479; called by muse, mutect2, varscan2
- SLC30A3 | c.1150G>A p.E384K | Missense Mutation (SNP) | VAF 277/389 reads (71%) | SIFT tolerated (0.07); PolyPhen benign (0.052); catalogued as COSV51986348, COSV51986791; called by muse, mutect2, varscan2
- SLC30A4 | c.752C>T p.S251L | Missense Mutation (SNP) | VAF 106/280 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.197); catalogued as COSV56006396, COSV56007613; called by muse, mutect2, varscan2
- SLC45A4 | c.29C>T p.P10L | Missense Mutation (SNP) | VAF 195/315 reads (62%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.012); catalogued as rs1310149542; called by muse, mutect2, varscan2
- SLC4A10 | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 251/389 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.561); catalogued as COSV55768672; called by muse, mutect2, varscan2
- SLC4A5 | c.885G>A p.M295I | Missense Mutation (SNP) | VAF 225/356 reads (63%) | SIFT tolerated (0.08); PolyPhen benign (0.034); catalogued as rs747773241; called by muse, mutect2, varscan2
- SLC5A12 | c.1118C>T p.S373F | Missense Mutation (SNP) | VAF 77/182 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54823503; called by muse, mutect2, varscan2
- SLC8A1 | c.2642G>A p.G881E | Missense Mutation (SNP) | VAF 376/538 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867120963, COSV60478411; called by muse, mutect2, varscan2
- SLCO1B3 | c.865G>A p.E289K | Missense Mutation (SNP) | VAF 42/108 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.088); catalogued as COSV53938763, COSV53947461; called by muse, mutect2, varscan2
- SLCO1C1 | c.944C>T p.S315F | Missense Mutation (SNP) | VAF 79/147 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.225); catalogued as COSV56878843; called by muse, mutect2, varscan2
- SLFN12L | c.1666C>T p.R556C (on ENST00000260908 / NM_001363830.1; = p.R574C on NM_001195790.1) | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as rs966521488; called by muse, mutect2, varscan2
- SMAD1 | c.668C>T p.P223L | Missense Mutation (SNP) | VAF 143/143 reads (100%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.558); catalogued as rs931493385; called by muse, mutect2, varscan2
- SPAG17 | c.5167C>T p.P1723S | Missense Mutation (SNP) | VAF 71/196 reads (36%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.999); catalogued as rs750241194, COSV60453678; called by muse, mutect2, varscan2
- SPAG17 | c.3160G>A p.E1054K | Missense Mutation (SNP) | VAF 93/154 reads (60%) | SIFT tolerated (0.67); PolyPhen benign (0.015); catalogued as COSV60453829; called by muse, mutect2, varscan2
- SPEF2 | c.4438G>A p.A1480T | Missense Mutation (SNP) | VAF 118/118 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.093); catalogued as rs756993685; called by muse, mutect2, varscan2
- SPEG | c.9388C>T p.P3130S | Missense Mutation (SNP) | VAF 187/339 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100404805; called by muse, mutect2, varscan2
- SPEG | c.9389C>T p.P3130L | Missense Mutation (SNP) | VAF 192/343 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1376293618, COSV56663052; called by muse, mutect2, varscan2
- SPHKAP | c.3412G>A p.E1138K | Missense Mutation (SNP) | VAF 279/433 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60884723; called by muse, mutect2, varscan2
- SPNS1 | c.940G>A p.G314R | Missense Mutation (SNP) | VAF 308/559 reads (55%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.527); catalogued as rs1157132333; called by muse, mutect2, varscan2
- SPOCK1 | c.490C>T p.H164Y | Missense Mutation (SNP) | VAF 83/301 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as rs780813471, COSV56440151; called by muse, mutect2, varscan2
- SPRYD3 | c.89G>A p.R30Q | Missense Mutation (SNP) | VAF 176/444 reads (40%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.982); catalogued as rs1320463051; called by muse, mutect2, varscan2
- SPTB | c.1573G>A p.E525K | Missense Mutation (SNP) | VAF 271/447 reads (61%) | SIFT deleterious (0.01); PolyPhen benign (0.384); catalogued as rs55752508, COSV67630267; called by muse, mutect2, varscan2
- SSTR1 | c.1045G>A p.E349K | Missense Mutation (SNP) | VAF 289/467 reads (62%) | SIFT deleterious (0.04); PolyPhen benign (0.097); catalogued as COSV99942952; called by muse, mutect2, varscan2
- ST18 | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 73/146 reads (50%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV52483156, COSV99388065; called by muse, mutect2, varscan2
- STAB2 | c.2249G>A p.G750E | Missense Mutation (SNP) | VAF 164/276 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as rs267603273, COSV66336543; called by muse, mutect2, varscan2
- STAG3 | c.3046T>C p.S1016P | Missense Mutation (SNP) | VAF 85/176 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs779587903, COSV57933450; called by muse, mutect2, varscan2
- STK11IP | c.1796C>T p.S599L | Missense Mutation (SNP) | VAF 179/532 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs1041555539; called by muse, mutect2, varscan2
- SUSD2 | c.1234G>A p.D412N | Missense Mutation (SNP) | VAF 687/688 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as rs374550310, COSV104420822; called by muse, mutect2, varscan2
- SYCE1 | c.856G>A p.G286R (on ENST00000343131 / NM_001143764.3; = p.G250R on NM_130784.3) | Missense Mutation (SNP) | VAF 115/210 reads (55%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.918); catalogued as COSV58216791; called by muse, mutect2, varscan2
- SYNE4 | c.871G>A p.A291T | Missense Mutation (SNP) | VAF 429/670 reads (64%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1255370457; called by muse, mutect2, varscan2
- TAGAP | c.1445G>A p.R482K | Missense Mutation (SNP) | VAF 268/270 reads (99%) | SIFT tolerated (0.5); PolyPhen benign (0.038); catalogued as COSV100487463; called by muse, mutect2, varscan2
- TAS1R2 | c.56C>T p.A19V | Missense Mutation (SNP) | VAF 336/520 reads (65%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.162); catalogued as rs753816644; called by muse, mutect2, varscan2
- TBC1D21 | c.712C>T p.P238S | Missense Mutation (SNP) | VAF 304/304 reads (100%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.999); catalogued as rs147755668; called by muse, mutect2, varscan2
- TENM4 | c.8170G>A p.E2724K | Missense Mutation (SNP) | VAF 294/507 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99572869; called by muse, mutect2, varscan2
- TEX101 | c.210G>A p.G70= (on ENST00000598265 / NM_001130011.3; = p.G88= on NM_031451.4) | Splice Region (SNP) | VAF 87/249 reads (35%) | catalogued as COSV53661390; called by muse, mutect2, varscan2
- TEX13C | c.1585G>A p.D529N | Missense Mutation (SNP) | VAF 363/369 reads (98%) | SIFT tolerated (0.84); catalogued as rs1278877568, COSV52468498; called by muse, mutect2, varscan2
- TGM5 | c.726G>A p.W242* (on ENST00000220420 / NM_201631.4; = p.W160* on NM_004245.4) | Nonsense Mutation (SNP) | VAF 159/339 reads (47%) | catalogued as COSV55011848; called by muse, mutect2, varscan2
- THSD7A | c.1522C>T p.P508S | Missense Mutation (SNP) | VAF 93/233 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.303); catalogued as COSV70263553; called by muse, mutect2, varscan2
- THSD7B | c.2362G>A p.E788K | Missense Mutation (SNP) | VAF 174/278 reads (63%) | SIFT deleterious (0.05); PolyPhen benign (0.393); catalogued as rs910707370; called by muse, varscan2
- TLR4 | c.941C>T p.S314F (on ENST00000355622 / NM_138554.5; = p.S274F on NM_003266.4) | Missense Mutation (SNP) | VAF 91/91 reads (100%) | SIFT tolerated (0.11); PolyPhen benign (0.025); catalogued as rs1421030523, COSV62923339; called by muse, mutect2, varscan2
- TLR4 | c.1615C>T p.P539S (on ENST00000355622 / NM_138554.5; = p.P499S on NM_003266.4) | Missense Mutation (SNP) | VAF 198/198 reads (100%) | SIFT tolerated (0.45); PolyPhen benign (0.033); catalogued as COSV62924105; called by muse, mutect2, varscan2
- TMEM119 | c.140C>T p.S47L | Missense Mutation (SNP) | VAF 282/784 reads (36%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.579); catalogued as rs546679439; called by muse, mutect2
- TNFRSF13B | c.746G>A p.G249E | Missense Mutation (SNP) | VAF 435/435 reads (100%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs1321374279; called by muse, mutect2, varscan2
- TNFSF8 | c.469G>A p.D157N | Missense Mutation (SNP) | VAF 314/316 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1206651308, COSV99801639; called by muse, mutect2, varscan2
- TNIK | c.2258G>A p.G753E | Missense Mutation (SNP) | VAF 128/362 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52672686; called by muse, mutect2, varscan2
- TNNT3 | c.40G>A p.E14K | Missense Mutation (SNP) | VAF 131/283 reads (46%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.305); catalogued as rs768888979, COSV53489377; called by muse, mutect2, varscan2
- TNS2 | c.3037C>T p.R1013C (on ENST00000314250 / NM_170754.4; = p.R1023C on NM_015319.2) | Missense Mutation (SNP) | VAF 469/797 reads (59%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.897); catalogued as rs142983356; called by muse, mutect2, varscan2
- TNS4 | c.560C>T p.S187F | Missense Mutation (SNP) | VAF 418/620 reads (67%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.691); catalogued as COSV54183276; called by muse, mutect2, varscan2
- TNXB | c.12221C>T p.S4074L (on ENST00000647633; = p.S3827L on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 688/689 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1008389232, COSV64477509; called by muse, mutect2, varscan2
- TP63 | c.398C>T p.P133L | Missense Mutation (SNP) | VAF 192/597 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV53208433; called by muse, mutect2, varscan2
- TRAV20 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 99/318 reads (31%) | SIFT tolerated (0.47); PolyPhen benign (0.012); catalogued as rs1453037638; called by muse, mutect2, varscan2
- TSHZ2 | c.2080C>T p.P694S | Missense Mutation (SNP) | VAF 427/641 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61587213; called by muse, mutect2, varscan2
- TSPAN8 | c.201G>A p.M67I | Missense Mutation (SNP) | VAF 178/316 reads (56%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.959); catalogued as COSV56081104; called by muse, mutect2
- TTN | c.100568G>A p.R33523H (on ENST00000591111; = p.R26099H on NM_003319.4) | Missense Mutation (SNP) | VAF 327/500 reads (65%) | PolyPhen benign (0.003); catalogued as rs768358201; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.53897G>A p.G17966E (on ENST00000591111; = p.G10542E on NM_003319.4) | Missense Mutation (SNP) | VAF 189/286 reads (66%) | PolyPhen probably damaging (1); catalogued as COSV100614261; called by muse, mutect2, varscan2
- TTN | c.40006G>A p.D13336N (on ENST00000591111; = p.D5912N on NM_003319.4) | Missense Mutation (SNP) | VAF 126/211 reads (60%) | PolyPhen possibly damaging (0.892); catalogued as rs778989426; called by muse, mutect2, varscan2
- TTN | c.31603+1G>A p.X10535_splice (on ENST00000591111; = p.X9608_splice on NM_133378.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 55/192 reads (29%) | catalogued as rs376018437, COSV60045069; called by muse, mutect2, varscan2
- TTN | c.12289C>T p.L4097F (on ENST00000591111; = p.L4051F on NM_003319.4) | Missense Mutation (SNP) | VAF 158/419 reads (38%) | catalogued as COSV59922373; called by muse, mutect2, varscan2
- TTN | c.415C>T p.R139W | Missense Mutation (SNP) | VAF 132/443 reads (30%) | PolyPhen benign (0.057); catalogued as rs752970602, COSV59913211, COSV60149531; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UBIAD1 | c.893G>A p.R298K | Missense Mutation (SNP) | VAF 189/525 reads (36%) | SIFT tolerated (0.77); PolyPhen benign (0.085); catalogued as rs142284333; called by muse, mutect2, varscan2
- UBR3 | c.1431G>A p.M477I | Missense Mutation (SNP) | VAF 101/192 reads (53%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.838); catalogued as COSV55845933; called by muse, mutect2, varscan2
- UGT1A7 | c.365C>T p.S122L | Missense Mutation (SNP) | VAF 62/156 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.044); catalogued as rs772862316; called by muse, varscan2
- UGT2B4 | c.787G>A p.D263N | Missense Mutation (SNP) | VAF 172/172 reads (100%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as COSV59315085; called by muse, mutect2, varscan2
- UNC13C | c.1778G>A p.G593E | Missense Mutation (SNP) | VAF 91/178 reads (51%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.036); catalogued as rs779586050, COSV52851745; called by muse, mutect2, varscan2
- UNC13C | c.4917G>A p.M1639I | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.1); catalogued as COSV52845159, COSV52879999; called by muse, mutect2, varscan2
- USP2 | c.1123C>T p.R375* | Nonsense Mutation (SNP) | VAF 125/125 reads (100%) | catalogued as COSV52730185; called by muse, mutect2, varscan2
- USP35 | c.1019C>T p.S340F | Missense Mutation (SNP) | VAF 111/319 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs777496605; called by muse, mutect2, varscan2
- VPS13B | c.4821G>A p.Q1607= | Splice Region (SNP) | VAF 103/158 reads (65%) | catalogued as COSV62136530; called by muse, mutect2, varscan2
- VWC2 | c.340C>T p.R114C | Missense Mutation (SNP) | VAF 242/477 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.353); catalogued as rs1335556723; called by muse, mutect2, varscan2
- VWDE | c.1687G>A p.G563R | Missense Mutation (SNP) | VAF 76/183 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1015058953; called by muse, mutect2, varscan2
- VWF | c.1741G>A p.E581K | Missense Mutation (SNP) | VAF 175/447 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.339); catalogued as rs1206640514; called by muse, mutect2, varscan2
- WDFY4 | c.3519G>A p.M1173I | Missense Mutation (SNP) | VAF 266/415 reads (64%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as COSV57456350; called by muse, mutect2, varscan2
- WDR49 | c.784C>T p.R262* (on ENST00000308378 / NM_001366158.1; = p.R603* on NM_001348951.2 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 49/171 reads (29%) | catalogued as rs200139077; called by muse, mutect2, varscan2
- WFDC13 | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 235/383 reads (61%) | SIFT tolerated (0.17); PolyPhen benign (0.237); catalogued as COSV57913634; called by muse, mutect2, varscan2
- WFDC8 | c.385G>A p.E129K | Missense Mutation (SNP) | VAF 257/399 reads (64%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as rs201744082, COSV51490643; called by muse, mutect2, varscan2
- WIZ | c.1469C>T p.P490L | Missense Mutation (SNP) | VAF 116/509 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1361482436; called by muse, mutect2, varscan2
- WNK1 | c.6152G>A p.S2051N (on ENST00000315939 / NM_018979.4; = p.S1803N on NM_014823.3) | Missense Mutation (SNP) | VAF 153/286 reads (53%) | SIFT tolerated (0.13); PolyPhen benign (0.111); catalogued as rs561238194; called by muse, mutect2, varscan2
- XDH | c.178C>T p.R60C | Missense Mutation (SNP) | VAF 211/321 reads (66%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.606); catalogued as rs184424277; called by muse, mutect2, varscan2
- XIRP2 | c.1852C>T p.R618* (on ENST00000628543; = p.R793* on NM_152381.6) | Nonsense Mutation (SNP) | VAF 127/396 reads (32%) | catalogued as rs374843236, COSV99743895; called by muse, mutect2, varscan2
- XIRP2 | c.2216G>A p.W739* (on ENST00000628543; = p.W914* on NM_152381.6) | Nonsense Mutation (SNP) | VAF 104/178 reads (58%) | catalogued as COSV54694499; called by muse, mutect2, varscan2
- ZBED9 | c.3383C>T p.S1128L | Missense Mutation (SNP) | VAF 146/148 reads (99%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as COSV71729148; called by muse, mutect2, varscan2
- ZBTB49 | c.1237C>T p.H413Y | Missense Mutation (SNP) | VAF 159/159 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759158107; called by muse, mutect2, varscan2
- ZCCHC10 | c.11C>T p.P4L | Missense Mutation (SNP) | VAF 296/422 reads (70%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.342); catalogued as COSV100147858; called by muse, mutect2, varscan2
- ZDHHC19 | c.911G>A p.G304E | Missense Mutation (SNP) | VAF 349/494 reads (71%) | SIFT deleterious (0); PolyPhen benign (0.298); catalogued as rs1271260461; called by muse, mutect2, varscan2
- ZFHX4 | c.7664C>T p.S2555F | Missense Mutation (SNP) | VAF 338/524 reads (65%) | SIFT tolerated (0.11); PolyPhen benign (0.191); catalogued as COSV50542768, COSV50639283; called by muse, mutect2, varscan2
- ZFPM2 | c.2465C>T p.S822F | Missense Mutation (SNP) | VAF 112/412 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV65875773; called by muse, mutect2, varscan2
- ZFPM2 | c.2801C>T p.S934F | Missense Mutation (SNP) | VAF 111/386 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.259); catalogued as COSV65874063; called by muse, varscan2
- ZIM3 | c.103G>A p.D35N | Missense Mutation (SNP) | VAF 214/214 reads (100%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV54140148; called by muse, mutect2, varscan2
- ZNF195 | c.562G>A p.D188N (on ENST00000399602 / NM_001130520.3; = p.D116N on NM_007152.5) | Missense Mutation (SNP) | VAF 52/104 reads (50%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.956); catalogued as COSV50007862; called by muse, mutect2, varscan2
- ZNF208 | c.3502C>T p.P1168S | Missense Mutation (SNP) | VAF 63/104 reads (61%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.912); catalogued as rs749724720; called by muse, mutect2, varscan2
- ZNF334 | c.1085C>T p.S362L | Missense Mutation (SNP) | VAF 119/392 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.847); catalogued as rs186911997; called by muse, mutect2, varscan2
- ZNF346 | c.322C>T p.H108Y | Missense Mutation (SNP) | VAF 156/262 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV99993084; called by muse, mutect2, varscan2
- ZNF385D | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 165/339 reads (49%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as COSV55746535; called by muse, mutect2, varscan2
- ZNF556 | c.823C>T p.R275* | Nonsense Mutation (SNP) | VAF 374/579 reads (65%) | catalogued as rs139842259; called by muse, mutect2, varscan2
- ZNF567 | c.616C>T p.P206S (on ENST00000536254 / NM_001322913.1; = p.P175S on NM_152603.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 239/370 reads (65%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs773247008; called by muse, mutect2, varscan2
- ZNF568 | c.1208C>T p.S403L | Missense Mutation (SNP) | VAF 119/467 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs759614987; called by muse, mutect2, varscan2
- ZNF568 | c.1738C>T p.R580* | Nonsense Mutation (SNP) | VAF 492/728 reads (68%) | catalogued as rs574434686, COSV71279130; called by muse, varscan2
- ZNF583 | c.1120C>T p.H374Y | Missense Mutation (SNP) | VAF 190/190 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52401658; called by muse, mutect2, varscan2
- ZNF679 | c.923C>T p.S308F | Missense Mutation (SNP) | VAF 72/142 reads (51%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.991); catalogued as COSV55379360; called by muse, mutect2, varscan2
- ZNF704 | c.293C>T p.P98L | Missense Mutation (SNP) | VAF 104/332 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100589531, COSV59919665; called by muse, mutect2, varscan2
- ZNF71 | c.526C>T p.H176Y | Missense Mutation (SNP) | VAF 359/359 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV60150550; called by muse, mutect2, varscan2
- ZNF71 | c.962C>T p.T321I | Missense Mutation (SNP) | VAF 333/334 reads (100%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as rs1393184928; called by muse, mutect2, varscan2
- ZNF80 | c.130C>T p.R44C | Missense Mutation (SNP) | VAF 168/500 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs143027025; called by muse, mutect2, varscan2
- ZNF831 | c.3158C>T p.S1053F | Missense Mutation (SNP) | VAF 195/659 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.758); catalogued as rs933866590, COSV64045149, COSV64045307; called by muse, mutect2, varscan2
- ZSCAN20 | c.2461C>A p.P821T | Missense Mutation (SNP) | VAF 280/432 reads (65%) | SIFT deleterious (0.05); PolyPhen benign (0.009); catalogued as COSV100792716; called by muse, varscan2
- ABCA3 | c.4289C>T p.T1430I | Missense Mutation (SNP) | VAF 294/599 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ABCB5 | c.1918G>A p.E640K (on ENST00000404938 / NM_001163941.2; = p.E195K on NM_178559.6) | Missense Mutation (SNP) | VAF 103/217 reads (47%) | SIFT tolerated (0.53); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- ABCB8 | c.1237T>A p.S413T (on ENST00000297504 / NM_001282291.2; = p.S396T on NM_007188.5) | Missense Mutation (SNP) | VAF 139/303 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- ABCC8 | c.3710C>T p.S1237F | Missense Mutation (SNP) | VAF 150/311 reads (48%) | SIFT tolerated (0.9); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- AC013470.2 | c.232A>T p.R78* | Nonsense Mutation (SNP) | VAF 72/128 reads (56%) | called by muse, varscan2
- AC013470.2 | c.397G>A p.V133M | Missense Mutation (SNP) | VAF 44/110 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- AC013470.2 | c.398T>G p.V133G | Missense Mutation (SNP) | VAF 44/107 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- ACIN1 | c.2855C>T p.P952L | Missense Mutation (SNP) | VAF 262/423 reads (62%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.407); called by muse, mutect2, varscan2
- ACIN1 | c.947C>T p.P316L | Missense Mutation (SNP) | VAF 131/355 reads (37%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ACMSD | c.182G>A p.R61K | Missense Mutation (SNP) | VAF 181/271 reads (67%) | SIFT tolerated (0.95); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ADAM23 | c.1628G>C p.G543A | Missense Mutation (SNP) | VAF 158/246 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ADAM30 | c.1381G>A p.G461R | Missense Mutation (SNP) | VAF 301/487 reads (62%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAMTS14 | c.632C>T p.A211V | Missense Mutation (SNP) | VAF 220/372 reads (59%) | SIFT tolerated (0.09); PolyPhen benign (0.018); called by muse, varscan2
- ADAMTS6 | c.1483G>A p.G495R | Missense Mutation (SNP) | VAF 236/236 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- ADAMTS9 | c.5221G>A p.E1741K | Missense Mutation (SNP) | VAF 43/133 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ADGRF4 | c.473G>A p.G158E | Missense Mutation (SNP) | VAF 218/218 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADNP | c.338C>T p.T113I | Missense Mutation (SNP) | VAF 235/343 reads (69%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- AFP | c.1771T>C p.C591R | Missense Mutation (SNP) | VAF 186/186 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AFTPH | c.204T>G p.I68M | Missense Mutation (SNP) | VAF 75/261 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- AGFG1 | c.769G>A p.G257S | Missense Mutation (SNP) | VAF 67/317 reads (21%) | SIFT tolerated (0.52); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- AK7 | c.515C>T p.P172L | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.609); called by muse, mutect2, varscan2
- AKR1C3 | c.473G>A p.G158E | Missense Mutation (SNP) | VAF 147/254 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ANAPC1 | c.4024A>G p.R1342G | Missense Mutation (SNP) | VAF 53/222 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- ANK3 | c.9715G>T p.D3239Y | Missense Mutation (SNP) | VAF 218/352 reads (62%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.751); called by muse, mutect2, varscan2
- ANK3 | c.2608G>A p.E870K | Missense Mutation (SNP) | VAF 93/166 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.339); called by muse, mutect2, varscan2
- APOOL | c.403T>A p.F135I | Missense Mutation (SNP) | VAF 141/142 reads (99%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- AQP1 | c.712C>A p.L238I | Missense Mutation (SNP) | VAF 41/313 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARAP2 | c.5041G>A p.E1681K | Missense Mutation (SNP) | VAF 111/111 reads (100%) | SIFT tolerated (0.34); PolyPhen benign (0.182); called by muse, mutect2, varscan2
- ARFGEF2 | c.3590C>T p.P1197L | Missense Mutation (SNP) | VAF 202/298 reads (68%) | SIFT tolerated (0.23); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- ARHGAP22 | c.722C>T p.P241L | Missense Mutation (SNP) | VAF 327/542 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARHGAP23 | c.1304C>G p.A435G | Missense Mutation (SNP) | VAF 644/896 reads (72%) | SIFT deleterious (0); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- ARHGAP23 | c.1589G>A p.G530D | Missense Mutation (SNP) | VAF 208/690 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ARHGAP9 | c.249G>A p.M83I | Missense Mutation (SNP) | VAF 241/377 reads (64%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARHGEF33 | c.284C>T p.S95F | Missense Mutation (SNP) | VAF 110/391 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); called by muse, mutect2, varscan2
- ARIH2 | c.1082C>T p.A361V | Missense Mutation (SNP) | VAF 120/266 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ARL1 | c.92C>T p.T31I | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARMC3 | c.661G>A p.D221N | Missense Mutation (SNP) | VAF 48/129 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- ASAP3 | c.151A>C p.I51L | Missense Mutation (SNP) | VAF 104/313 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ASIC5 | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 202/202 reads (100%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- ASTE1 | c.1474A>T p.M492L | Missense Mutation (SNP) | VAF 163/253 reads (64%) | SIFT tolerated (0.24); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- ATM | c.7523G>A p.G2508E | Missense Mutation (SNP) | VAF 91/145 reads (63%) | SIFT tolerated (0.27); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ATP2A2 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 137/236 reads (58%) | SIFT tolerated (0.28); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- ATP5PD | c.120C>T p.S40= | Splice Region (SNP) | VAF 146/442 reads (33%) | called by muse, mutect2, varscan2
- ATP6V1H | c.1399C>T p.L467F | Missense Mutation (SNP) | VAF 206/329 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- ATRNL1 | c.4022T>C p.L1341P | Missense Mutation (SNP) | VAF 49/95 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ATXN10 | c.203C>T p.P68L | Missense Mutation (SNP) | VAF 425/426 reads (100%) | SIFT deleterious (0.02); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- ATXN7L1 | c.17C>T p.S6F | Missense Mutation (SNP) | VAF 78/173 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- ATXN7L1 | c.16T>G p.S6A | Missense Mutation (SNP) | VAF 78/171 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- AVEN | c.59C>T p.P20L | Missense Mutation (SNP) | VAF 186/337 reads (55%) | SIFT tolerated, low confidence (0.32); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BAHD1 | c.1459G>A p.E487K | Missense Mutation (SNP) | VAF 143/298 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- BMPER | c.988G>A p.E330K | Missense Mutation (SNP) | VAF 86/187 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.338); called by muse, mutect2, varscan2
- BMPR2 | c.989C>T p.S330F | Missense Mutation (SNP) | VAF 39/171 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- BRWD3 | c.3451A>T p.I1151F | Missense Mutation (SNP) | VAF 197/197 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- BSN | c.9100G>A p.D3034N | Missense Mutation (SNP) | VAF 227/474 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.083); called by muse, varscan2
- BSN | c.9284C>T p.P3095L | Missense Mutation (SNP) | VAF 234/497 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.073); called by muse, varscan2
- BTBD11 | c.352C>T p.P118S | Missense Mutation (SNP) | VAF 358/613 reads (58%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2, varscan2
- C10orf90 | c.1081C>T p.P361S | Missense Mutation (SNP) | VAF 162/287 reads (56%) | SIFT tolerated (0.08); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- C1QTNF1 | c.190C>T p.Q64* | Nonsense Mutation (SNP) | VAF 352/753 reads (47%) | called by muse, mutect2
- C1orf105 | c.355C>T p.Q119* | Nonsense Mutation (SNP) | VAF 230/230 reads (100%) | called by muse, mutect2, varscan2
- C2CD5 | c.677del p.F226Sfs*9 | Frame Shift Del (DEL) | VAF 152/464 reads (33%) | called by mutect2, pindel, varscan2
- CA4 | c.243G>A p.W81* | Nonsense Mutation (SNP) | VAF 232/364 reads (64%) | called by muse, mutect2, varscan2
- CACNG4 | c.824C>T p.S275F | Missense Mutation (SNP) | VAF 184/1258 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- CADM2 | c.170C>T p.S57L (on ENST00000407528 / NM_001167674.2; = p.S59L on NM_153184.4) | Missense Mutation (SNP) | VAF 104/250 reads (42%) | SIFT tolerated (0.81); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CAMKK2 | c.443C>T p.S148F | Missense Mutation (SNP) | VAF 217/360 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- CAMTA2 | c.667C>T p.R223* | Nonsense Mutation (SNP) | VAF 345/346 reads (100%) | called by muse, mutect2, varscan2
- CASKIN2 | c.947C>T p.P316L | Missense Mutation (SNP) | VAF 436/746 reads (58%) | SIFT deleterious (0.03); PolyPhen benign (0.239); called by muse, varscan2
- CASP5 | c.947G>A p.R316K | Missense Mutation (SNP) | VAF 129/225 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CBX3 | c.263G>T p.G88V | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- CBX4 | c.1220C>T p.S407F | Missense Mutation (SNP) | VAF 662/1148 reads (58%) | SIFT tolerated (0.11); PolyPhen benign (0.364); called by muse, varscan2
- CCDC148 | c.624T>A p.S208R | Missense Mutation (SNP) | VAF 13/241 reads (5%) | SIFT tolerated (0.52); PolyPhen benign (0.003); called by muse, mutect2
- CCDC22 | c.152C>T p.S51F | Missense Mutation (SNP) | VAF 258/262 reads (98%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- CCDC57 | c.1744C>T p.L582F | Missense Mutation (SNP) | VAF 43/166 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.519); called by muse, mutect2, varscan2
- CCDC71 | c.901C>T p.R301* | Nonsense Mutation (SNP) | VAF 214/441 reads (49%) | called by muse, mutect2, varscan2
- CCNY | c.520T>C p.F174L | Missense Mutation (SNP) | VAF 126/281 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CD300H | c.101C>T p.A34V | Missense Mutation (SNP) | VAF 91/720 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- CD93 | c.1346C>T p.S449F | Missense Mutation (SNP) | VAF 223/432 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- CDC40 | c.1552C>T p.P518S | Missense Mutation (SNP) | VAF 84/84 reads (100%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CDC42EP2 | c.167C>T p.S56F | Missense Mutation (SNP) | VAF 244/424 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, varscan2
- CDH23 | c.8614G>A p.D2872N | Missense Mutation (SNP) | VAF 335/543 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CDR2L | c.931C>T p.H311Y | Missense Mutation (SNP) | VAF 202/1442 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- CEP170B | c.2377C>A p.P793T (on ENST00000453495; = p.P722T on NM_015005.3) | Missense Mutation (SNP) | VAF 239/530 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- CFAP61 | c.3037C>T p.L1013F | Missense Mutation (SNP) | VAF 105/213 reads (49%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- CFTR | c.2702A>C p.N901T | Missense Mutation (SNP) | VAF 52/133 reads (39%) | SIFT tolerated (0.29); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CHD5 | c.4601C>T p.P1534L | Missense Mutation (SNP) | VAF 207/657 reads (32%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- CHD9 | c.3539C>T p.S1180F | Missense Mutation (SNP) | VAF 138/139 reads (99%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- CHIA | c.1105G>T p.G369C (on ENST00000343320; = p.G261C on NM_021797.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/558 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CIT | c.5980C>T p.P1994S | Missense Mutation (SNP) | VAF 301/530 reads (57%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CLEC2B | c.428T>C p.I143T | Missense Mutation (SNP) | VAF 97/227 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CNGB3 | c.814C>T p.Q272* | Nonsense Mutation (SNP) | VAF 112/209 reads (54%) | called by muse, mutect2, varscan2
- CNTNAP2 | c.939G>A p.E313= | Splice Region (SNP) | VAF 47/93 reads (51%) | called by muse, mutect2, varscan2
- COL16A1 | c.1004C>T p.P335L | Missense Mutation (SNP) | VAF 222/377 reads (59%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL19A1 | c.239G>A p.G80E | Missense Mutation (SNP) | VAF 99/99 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL1A2 | c.1147C>T p.P383S | Missense Mutation (SNP) | VAF 117/260 reads (45%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL4A5 | c.364C>T p.P122S | Missense Mutation (SNP) | VAF 204/204 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COLCA2 | c.421G>A p.D141N | Missense Mutation (SNP) | VAF 151/153 reads (99%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- COPS7A | c.158G>A p.R53K | Missense Mutation (SNP) | VAF 130/211 reads (62%) | SIFT tolerated (0.64); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CROCC | c.4619C>T p.A1540V | Missense Mutation (SNP) | VAF 329/495 reads (66%) | SIFT tolerated (0.25); PolyPhen benign (0.234); called by muse, mutect2, varscan2
- CRYBG1 | c.385G>A p.G129R | Missense Mutation (SNP) | VAF 272/273 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CSNK2A1 | c.900C>A p.F300L | Missense Mutation (SNP) | VAF 134/402 reads (33%) | SIFT tolerated (0.59); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- CSTF1 | c.1091C>T p.T364I | Missense Mutation (SNP) | VAF 296/427 reads (69%) | SIFT deleterious (0); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- CUBN | c.2977del p.Y993Mfs*28 | Frame Shift Del (DEL) | VAF 72/195 reads (37%) | called by mutect2, pindel, varscan2
- CUX2 | c.405G>A p.W135* | Nonsense Mutation (SNP) | VAF 183/472 reads (39%) | called by muse, mutect2, varscan2
- CXorf66 | c.703G>A p.E235K | Missense Mutation (SNP) | VAF 340/341 reads (100%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CYP1A1 | c.454G>A p.A152T | Missense Mutation (SNP) | VAF 324/324 reads (100%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CYSTM1 | c.7C>T p.Q3* | Nonsense Mutation (SNP) | VAF 198/314 reads (63%) | called by muse, mutect2, varscan2
- DCANP1 | c.268C>T p.H90Y | Missense Mutation (SNP) | VAF 203/636 reads (32%) | SIFT tolerated, low confidence (0.97); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- DCDC2C | c.1030G>A p.E344K | Missense Mutation (SNP) | VAF 34/147 reads (23%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- DCLRE1A | c.292C>T p.P98S | Missense Mutation (SNP) | VAF 122/226 reads (54%) | SIFT tolerated (0.1); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- DENND11 | c.344C>T p.S115F | Missense Mutation (SNP) | VAF 80/163 reads (49%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.573); called by muse, mutect2, varscan2
- DENND3 | c.1126C>T p.H376Y | Missense Mutation (SNP) | VAF 64/190 reads (34%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.565); called by muse, varscan2
- DGKI | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 112/258 reads (43%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- DIS3L2 | c.1034C>T p.S345F | Missense Mutation (SNP) | VAF 260/391 reads (66%) | SIFT deleterious (0); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- DLG5 | c.5606A>C p.Q1869P | Missense Mutation (SNP) | VAF 180/529 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- DNAH7 | c.4362G>C p.M1454I | Missense Mutation (SNP) | VAF 61/223 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNAI2 | c.990C>T p.P330= | Splice Region (SNP) | VAF 384/596 reads (64%) | called by muse, mutect2
- DNAJB12 | c.734G>A p.G245D (on ENST00000338820; = p.G211D on NM_017626.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 130/383 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAJC13 | c.3412C>T p.P1138S | Missense Mutation (SNP) | VAF 43/199 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DNAJC17 | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 119/241 reads (49%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- DNALI1 | c.230C>T p.T77I (on ENST00000296218; = p.T55I on NM_003462.5) | Missense Mutation (SNP) | VAF 167/564 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2
- DOCK2 | c.635A>T p.Y212F | Missense Mutation (SNP) | VAF 201/298 reads (67%) | SIFT tolerated (0.66); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DOT1L | c.1393C>T p.P465S | Missense Mutation (SNP) | VAF 215/581 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DPT | c.331C>G p.L111V | Missense Mutation (SNP) | VAF 30/331 reads (9%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.551); called by muse, mutect2
- DPYSL5 | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 126/395 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DSP | c.7685C>T p.S2562F | Missense Mutation (SNP) | VAF 340/341 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- DST | c.9971A>T p.K3324I | Missense Mutation (SNP) | VAF 115/115 reads (100%) | SIFT deleterious (0.01); PolyPhen benign (0.428); called by muse, mutect2, varscan2
- DTX3L | c.1175T>C p.L392S | Missense Mutation (SNP) | VAF 75/191 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- DUOX1 | c.1932G>A p.M644I | Missense Mutation (SNP) | VAF 102/211 reads (48%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2, varscan2
- DUSP8 | c.353G>A p.S118N | Missense Mutation (SNP) | VAF 149/321 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- DYNAP | c.220C>T p.P74S (on ENST00000321600; = p.P48S on NM_173629.3) | Missense Mutation (SNP) | VAF 188/188 reads (100%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ECHDC3 | c.44C>T p.P15L | Missense Mutation (SNP) | VAF 347/589 reads (59%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- EFCAB7 | c.1805A>G p.K602R | Missense Mutation (SNP) | VAF 46/150 reads (31%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- EGR1 | c.145C>T p.L49F | Missense Mutation (SNP) | VAF 235/782 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.796); called by muse, varscan2
- EMCN | c.187G>A p.G63R | Missense Mutation (SNP) | VAF 62/62 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- EPB41L1 | c.2317C>T p.P773S | Missense Mutation (SNP) | VAF 287/454 reads (63%) | SIFT tolerated (0.55); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- EPHA4 | c.2515G>A p.E839K | Missense Mutation (SNP) | VAF 75/260 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ERBB2 | c.1009C>T p.P337S | Missense Mutation (SNP) | VAF 91/360 reads (25%) | SIFT tolerated (0.71); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ERBB4 | c.3082T>A p.F1028I | Missense Mutation (SNP) | VAF 93/282 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- ERCC3 | c.88C>T p.P30S | Missense Mutation (SNP) | VAF 419/584 reads (72%) | SIFT tolerated (0.83); PolyPhen benign (0); called by muse, mutect2, varscan2
- ERMP1 | c.733T>C p.F245L | Missense Mutation (SNP) | VAF 182/183 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ESPN | c.490G>A p.G164R | Missense Mutation (SNP) | VAF 127/427 reads (30%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.778); called by muse, mutect2, varscan2
- EXPH5 | c.3833T>C p.L1278P | Missense Mutation (SNP) | VAF 130/204 reads (64%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.749); called by muse, mutect2, varscan2
- EYA4 | c.1111G>A p.D371N (on ENST00000531901 / NM_001301013.1; = p.D365N on NM_004100.5) | Missense Mutation (SNP) | VAF 143/143 reads (100%) | SIFT tolerated (0.06); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- FAM104A | c.403G>A p.G135S | Missense Mutation (SNP) | VAF 827/1267 reads (65%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FAM161A | c.443C>T p.S148F | Missense Mutation (SNP) | VAF 75/248 reads (30%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.752); called by muse, mutect2, varscan2
- FAM170A | c.721G>A p.E241K | Missense Mutation (SNP) | VAF 327/492 reads (66%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- FAM171A2 | c.914C>T p.S305L | Missense Mutation (SNP) | VAF 130/499 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- FAM227B | c.1347G>A p.R449= | Splice Region (SNP) | VAF 44/116 reads (38%) | called by muse, mutect2, varscan2
- FAM25C | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 182/398 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- FAM47C | c.2969G>A p.G990D | Missense Mutation (SNP) | VAF 117/118 reads (99%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAM83B | c.2597G>A p.R866K | Missense Mutation (SNP) | VAF 449/450 reads (100%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FBF1 | c.50C>T p.P17L (on ENST00000586717; = p.P31L on NM_001319193.1) | Missense Mutation (SNP) | VAF 176/549 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FBXW7 | c.1406T>C p.L469P (on ENST00000281708 / NM_001349798.2; = p.L389P on NM_018315.5) | Missense Mutation (SNP) | VAF 133/134 reads (99%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- FGFR1 | c.815A>G p.N272S (on ENST00000447712 / NM_023110.3; = p.N270S on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/172 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- FGFR2 | c.2355C>A p.D785E | Missense Mutation (SNP) | VAF 95/264 reads (36%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- FGFR4 | c.1358A>G p.D453G | Missense Mutation (SNP) | VAF 211/661 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- FHIT | c.140T>A p.F47Y | Missense Mutation (SNP) | VAF 165/370 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- FKBP7 | c.563C>T p.S188L | Missense Mutation (SNP) | VAF 85/173 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- FLNB | c.6848C>A p.P2283H | Missense Mutation (SNP) | VAF 126/265 reads (48%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- FLNC | c.4361G>A p.G1454E | Missense Mutation (SNP) | VAF 253/497 reads (51%) | SIFT tolerated (0.15); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- FMO2 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 141/141 reads (100%) | SIFT tolerated (0.06); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- FSIP2 | c.14494G>A p.E4832K | Missense Mutation (SNP) | VAF 45/75 reads (60%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- FSIP2 | c.15684G>C p.M5228I | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated (0.36); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- FUT3 | c.646C>T p.H216Y | Missense Mutation (SNP) | VAF 243/686 reads (35%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.54); called by muse, mutect2, varscan2
- FYB2 | c.637C>T p.P213S | Missense Mutation (SNP) | VAF 143/412 reads (35%) | SIFT tolerated (0.5); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- GABRA2 | c.833C>T p.S278F | Missense Mutation (SNP) | VAF 129/129 reads (100%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GABRA5 | c.581-1G>A p.X194_splice | Splice Site (SNP) | VAF 60/140 reads (43%) | called by muse, varscan2
- GABRE | c.970G>A p.G324S | Missense Mutation (SNP) | VAF 364/364 reads (100%) | SIFT tolerated (1); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- GABRE | c.969G>T p.L323F | Missense Mutation (SNP) | VAF 360/360 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GALNT16 | c.592G>A p.G198R | Missense Mutation (SNP) | VAF 218/377 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GALR2 | c.56G>A p.G19E | Missense Mutation (SNP) | VAF 989/1486 reads (67%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- GIMAP2 | c.632G>A p.G211D | Missense Mutation (SNP) | VAF 91/234 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- GLI2 | c.2378C>T p.T793I (on ENST00000361492 / NM_001374353.1; = p.T810I on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 462/738 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- GMEB2 | c.98C>T p.T33I | Missense Mutation (SNP) | VAF 103/363 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- GOLGA6L22 | c.2326G>A p.E776K | Missense Mutation (SNP) | VAF 44/250 reads (18%) | SIFT deleterious (0); called by muse, mutect2, varscan2
- GPD1L | c.674C>T p.T225I | Missense Mutation (SNP) | VAF 172/386 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GPHA2 | c.70C>T p.Q24* | Nonsense Mutation (SNP) | VAF 206/380 reads (54%) | called by muse, mutect2, varscan2
- GPHN | c.2140C>T p.P714S (on ENST00000315266 / NM_001377519.1; = p.P747S on NM_020806.5) | Missense Mutation (SNP) | VAF 309/483 reads (64%) | SIFT tolerated (0.12); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- GPR132 | c.23A>G p.N8S | Missense Mutation (SNP) | VAF 118/256 reads (46%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0); called by muse, mutect2, varscan2
- GPR171 | c.578C>T p.A193V | Missense Mutation (SNP) | VAF 59/179 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- GPR179 | c.2407G>A p.E803K (on ENST00000621958; = p.E802K on NM_001004334.4) | Missense Mutation (SNP) | VAF 522/777 reads (67%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- GPR25 | c.794C>T p.A265V | Missense Mutation (SNP) | VAF 424/424 reads (100%) | SIFT tolerated (0.31); PolyPhen benign (0.017); called by muse, varscan2
- GRAMD1B | c.1211A>G p.E404G | Missense Mutation (SNP) | VAF 130/130 reads (100%) | SIFT tolerated (0.12); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- GRB10 | c.1256C>G p.P419R (on ENST00000398812; = p.P373R on NM_001001549.3) | Missense Mutation (SNP) | VAF 107/230 reads (47%) | SIFT tolerated (0.34); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- GTF2B | c.232G>A p.G78R | Missense Mutation (SNP) | VAF 30/245 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.413); called by muse, mutect2, varscan2
- HDAC4 | c.887C>T p.P296L | Missense Mutation (SNP) | VAF 168/522 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- HECTD1 | c.5132C>T p.S1711F | Missense Mutation (SNP) | VAF 220/339 reads (65%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- HECTD1 | c.1445C>T p.P482L | Missense Mutation (SNP) | VAF 99/170 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HERC1 | c.13594A>G p.I4532V | Missense Mutation (SNP) | VAF 85/218 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- HERC2 | c.2771G>A p.S924N | Missense Mutation (SNP) | VAF 126/235 reads (54%) | SIFT tolerated (0.12); PolyPhen benign (0.144); called by muse, mutect2, varscan2
- HIVEP1 | c.6371C>T p.S2124F | Missense Mutation (SNP) | VAF 222/222 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HNRNPA2B1 | c.391T>A p.Y131N (on ENST00000354667 / NM_031243.3; = p.Y119N on NM_002137.4) | Missense Mutation (SNP) | VAF 76/154 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HPS3 | c.1423A>G p.K475E | Missense Mutation (SNP) | VAF 89/149 reads (60%) | SIFT deleterious (0.02); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- HSPA9 | c.916C>T p.Q306* | Nonsense Mutation (SNP) | VAF 94/300 reads (31%) | called by muse, mutect2, varscan2
- HTRA1 | c.748G>A p.D250N | Missense Mutation (SNP) | VAF 117/200 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HYDIN | c.6706C>T p.L2236F | Missense Mutation (SNP) | VAF 203/226 reads (90%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); called by muse, varscan2
- IBTK | c.1451C>T p.S484F | Missense Mutation (SNP) | VAF 93/93 reads (100%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.646); called by muse, mutect2, varscan2
- IFT88 | c.1649T>C p.F550S (on ENST00000319980 / NM_001318493.2; = p.F541S on NM_006531.5 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 122/237 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- IGBP1P2 | c.205G>T p.D69Y | Missense Mutation (SNP) | VAF 128/475 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- IGHV3-64 | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 147/306 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- IGKV1-9 | c.349C>T p.P117S | Missense Mutation (SNP) | VAF 50/192 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IKZF5 | c.613G>T p.V205L | Missense Mutation (SNP) | VAF 106/282 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- IL13RA1 | c.511C>T p.H171Y | Missense Mutation (SNP) | VAF 116/116 reads (100%) | SIFT tolerated (0.05); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- IL21R | c.1532G>A p.G511E | Missense Mutation (SNP) | VAF 405/787 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IL22RA1 | c.1550C>T p.S517F | Missense Mutation (SNP) | VAF 402/654 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); called by muse, mutect2
- IL27RA | c.235C>T p.Q79* | Nonsense Mutation (SNP) | VAF 122/470 reads (26%) | called by muse, mutect2
- INSC | c.808G>A p.A270T | Missense Mutation (SNP) | VAF 112/240 reads (47%) | SIFT tolerated (0.42); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- IRS1 | c.2467G>T p.A823S | Missense Mutation (SNP) | VAF 314/508 reads (62%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- ITGA4 | c.3047A>G p.E1016G | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); called by muse, mutect2, varscan2
- ITGA9 | c.1308G>A p.M436I | Missense Mutation (SNP) | VAF 134/250 reads (54%) | SIFT tolerated (0.72); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ITPRID1 | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 162/352 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); called by muse, mutect2
- ITPRID2 | c.694C>T p.P232S | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ITPRIPL1 | c.1519C>T p.P507S (on ENST00000439118 / NM_001008949.3; = p.P515S on NM_178495.6) | Missense Mutation (SNP) | VAF 106/322 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- ITPRIPL1 | c.1520C>T p.P507L (on ENST00000439118 / NM_001008949.3; = p.P515L on NM_178495.6) | Missense Mutation (SNP) | VAF 108/327 reads (33%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- JAM2 | c.614C>T p.S205F | Missense Mutation (SNP) | VAF 96/206 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- JCAD | c.1612G>A p.G538R | Missense Mutation (SNP) | VAF 177/397 reads (45%) | SIFT tolerated (0.24); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- JPH3 | c.1161G>A p.R387= | Splice Region (SNP) | VAF 336/338 reads (99%) | called by muse, mutect2, varscan2
- KCNH8 | c.2321C>T p.S774F | Missense Mutation (SNP) | VAF 120/256 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.322); called by muse, mutect2, varscan2
- KCNK1 | c.770T>C p.L257P | Missense Mutation (SNP) | VAF 204/204 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KDM5A | c.1574T>C p.L525S | Missense Mutation (SNP) | VAF 226/554 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KEL | c.697C>T p.P233S | Missense Mutation (SNP) | VAF 125/276 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- KIAA1328 | c.11T>C p.V4A | Missense Mutation (SNP) | VAF 195/383 reads (51%) | SIFT tolerated (0.34); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- KIF1B | c.2413G>A p.E805K (on ENST00000377086 / NM_001365952.1; = p.E759K on NM_015074.3) | Missense Mutation (SNP) | VAF 123/421 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.052); called by muse, mutect2, varscan2
908 further variants in this file (317 protein-altering or splice-affecting, 534 silent, 57 other) are not listed here.
